Somatic mutation profile of tumor specimen TCGA-34-8454-01A (aliquot TCGA-34-8454-01A-11D-2323-08) from TCGA case TCGA-34-8454, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 62.7 years (22,913 days).
Specimen TCGA-34-8454-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 69bd5b81-eba0-4b55-8c72-ad1f1e31b8c0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-34-8454-10A (Blood Derived Normal), aliquot TCGA-34-8454-10A-01D-2323-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8adbc731-bf59-499c-85e2-a0ee6af7f5e1

The open-access MAF lists 592 somatic variants for this specimen: 435 protein-altering or splice-affecting, 146 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 376, Silent 146, Nonsense Mutation 28, Splice Site 12, Frame Shift Del 8, Splice Region 6, RNA 4, Frame Shift Ins 4, Intron 3, 5'Flank 2, 3'UTR 2, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KIAA0586 | c.2308C>T p.R770* (on ENST00000619416 / NM_001244190.2; = p.R709* on NM_014749.5) | Nonsense Mutation (SNP) | VAF 47/230 reads (20%) | catalogued as rs1064793157, CM1510289, COSV99708287; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1633G>C p.E545Q | Missense Mutation (SNP) | VAF 7/67 reads (10%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen possibly damaging (0.734); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: drug response / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PTEN | c.955dup p.T319Nfs*6 | Frame Shift Ins (INS) | VAF 33/89 reads (37%) | catalogued as rs786204892, CI075686, COSV64290023; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- SGCB | c.272G>T p.R91L | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs104893869, CM961270, CM983767, COSV101197703, COSV67341571; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.535C>T p.H179Y | Missense Mutation (SNP) | VAF 13/46 reads (28%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs587780070, CM067054, COSV52662617, COSV52668276, COSV52699993; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCA5 | c.3113_3116del p.Y1038Lfs*45 | Frame Shift Del (DEL) | VAF 8/46 reads (17%) | catalogued as rs781391905; called by mutect2, pindel, varscan2
- ABCB1 | c.209T>C p.L70P | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV99713529; called by muse, mutect2, varscan2
- ABCC5 | c.3235G>A p.E1079K | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT tolerated (0.78); PolyPhen benign (0.141); catalogued as COSV99657176; called by muse, mutect2, varscan2
- ABCD3 | c.336-2A>G p.X112_splice | Splice Site (SNP) | VAF 12/65 reads (18%) | catalogued as COSV100238994; called by muse, mutect2, varscan2
- AC013489.1 | c.922G>T p.E308* | Nonsense Mutation (SNP) | VAF 16/49 reads (33%) | catalogued as COSV99183884; called by muse, mutect2, varscan2
- ADAMTSL3 | c.2812C>T p.R938* | Nonsense Mutation (SNP) | VAF 45/162 reads (28%) | catalogued as COSV54448098, COSV54452887; called by muse, mutect2, varscan2
- ADGRG4 | c.564G>T p.W188C | Missense Mutation (SNP) | VAF 38/211 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV99795345, COSV99796015; called by muse, mutect2, varscan2
- ADGRG4 | c.6464C>T p.S2155L | Missense Mutation (SNP) | VAF 26/125 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV54955443, COSV99796016; called by muse, mutect2, varscan2
- AFDN | c.897G>T p.R299= | Splice Region (SNP) | VAF 35/163 reads (21%) | catalogued as rs1457628138, COSV100653208; called by muse, mutect2, varscan2
- AFF4 | c.3016G>T p.E1006* | Nonsense Mutation (SNP) | VAF 18/61 reads (30%) | catalogued as COSV54792919; called by muse, mutect2, varscan2
- AHDC1 | c.3357G>T p.W1119C | Missense Mutation (SNP) | VAF 31/163 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV55936644, COSV99899505; called by muse, mutect2, varscan2
- AL121899.2 | c.1431del p.K478Nfs*29 | Frame Shift Del (DEL) | VAF 21/121 reads (17%) | catalogued as COSV67350587; called by mutect2, pindel, varscan2
- ALMS1 | c.2005C>T p.H669Y | Missense Mutation (SNP) | VAF 26/125 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100042997; called by muse, mutect2, varscan2
- ANKMY2 | c.645T>A p.N215K | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100187185; called by muse, mutect2, varscan2
- ANP32E | c.775G>T p.A259S | Missense Mutation (SNP) | VAF 47/275 reads (17%) | SIFT tolerated (0.61); PolyPhen benign (0.036); catalogued as COSV100029728; called by muse, mutect2, varscan2
- AP1S1 | c.91A>G p.M31V | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV100522709; called by muse, mutect2
- APH1A | c.387T>A p.S129R | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.591); catalogued as COSV99354447; called by muse, mutect2, varscan2
- APOB | c.6223G>C p.E2075Q | Missense Mutation (SNP) | VAF 36/78 reads (46%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as COSV99266569; called by muse, mutect2, varscan2
- ARHGAP35 | c.1069G>T p.E357* | Nonsense Mutation (SNP) | VAF 28/80 reads (35%) | catalogued as COSV101351306; called by muse, mutect2, varscan2
- ARMCX1 | c.92G>C p.R31T | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.023); catalogued as COSV100863219; called by muse, mutect2, varscan2
- ASCL1 | c.424C>T p.R142W | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99902074; called by muse, mutect2, varscan2
- ASPM | c.1261C>G p.Q421E | Missense Mutation (SNP) | VAF 20/97 reads (21%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV99660726; called by muse, mutect2, varscan2
- ASPM | c.1109C>G p.S370C | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.339); catalogued as COSV99660727; called by muse, mutect2, varscan2
- ASXL2 | c.814G>A p.E272K | Missense Mutation (SNP) | VAF 31/206 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV55468976, COSV99078349; called by muse, mutect2, varscan2
- ATP4A | c.393T>A p.S131R | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT tolerated (0.22); PolyPhen benign (0.125); catalogued as COSV99382824; called by muse, mutect2, varscan2
- ATXN7 | c.2246C>T p.T749M | Missense Mutation (SNP) | VAF 21/96 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs376073882, COSV55751584; called by muse, mutect2, varscan2
- BABAM2 | c.219C>G p.F73L | Missense Mutation (SNP) | VAF 58/449 reads (13%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.992); catalogued as COSV100568286, COSV59617630; called by muse, mutect2, varscan2
- BAZ2B | c.457C>T p.H153Y | Missense Mutation (SNP) | VAF 20/86 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.079); catalogued as rs1272731178, COSV58601230; called by muse, mutect2, varscan2
- BCORL1 | c.4636C>G p.Q1546E | Missense Mutation (SNP) | VAF 49/187 reads (26%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.765); catalogued as COSV54393278, COSV99500098; called by muse, mutect2, varscan2
- BICC1 | c.2731G>T p.D911Y | Missense Mutation (SNP) | VAF 25/73 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100874877; called by muse, mutect2, varscan2
- BRI3BP | c.407A>T p.Y136F | Missense Mutation (SNP) | VAF 27/100 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100413109; called by muse, mutect2, varscan2
- BRINP3 | c.2156G>A p.R719H | Missense Mutation (SNP) | VAF 22/110 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs760188757, COSV66537031; called by muse, mutect2, varscan2
- BRMS1 | c.187G>A p.E63K | Missense Mutation (SNP) | VAF 65/453 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs1429183916, COSV100240324; called by muse, mutect2, varscan2
- BRWD3 | c.673A>G p.I225V | Missense Mutation (SNP) | VAF 39/160 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.51); catalogued as COSV100956275; called by muse, mutect2, varscan2
- BTNL3 | c.51A>G p.G17= | Splice Region (SNP) | VAF 14/53 reads (26%) | catalogued as COSV100732218; called by muse, varscan2
- C1GALT1C1 | c.142A>T p.N48Y | Missense Mutation (SNP) | VAF 31/139 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.346); catalogued as COSV100485629; called by muse, mutect2, varscan2
- C4BPA | c.1462G>C p.E488Q | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.596); catalogued as COSV65536354; called by muse, mutect2, varscan2
- C4orf50 | c.-2772G>T | Splice Region (SNP) | VAF 4/23 reads (17%) | catalogued as COSV101290908; called by muse, mutect2, varscan2
- CACNA1B | c.5536C>A p.P1846T | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT tolerated (0.21); PolyPhen benign (0.29); catalogued as COSV53121016, COSV99498448; called by muse, mutect2, varscan2
- CACNA1I | c.4035C>A p.N1345K | Missense Mutation (SNP) | VAF 23/111 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100360850; called by muse, mutect2, varscan2
- CALD1 | c.1942G>C p.E648Q (on ENST00000361675 / NM_033138.4; = p.E393Q on NM_004342.7) | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1488791128, COSV100724388; called by muse, mutect2, varscan2
- CARD6 | c.2836C>G p.Q946E | Missense Mutation (SNP) | VAF 63/321 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.084); catalogued as COSV54567402, COSV99620993; called by muse, mutect2, varscan2
- CARMIL2 | c.3705A>G p.Q1235= | Splice Region (SNP) | VAF 17/89 reads (19%) | catalogued as COSV99537861; called by muse, mutect2, varscan2
- CASK | c.518G>C p.G173A | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT tolerated (0.45); PolyPhen benign (0.014); catalogued as COSV100587424; called by muse, mutect2, varscan2
- CBLIF | c.80-2A>T p.X27_splice | Splice Site (SNP) | VAF 13/60 reads (22%) | catalogued as COSV99951016; called by muse, mutect2, varscan2
- CCDC170 | c.1562G>T p.R521L | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV53340589, COSV99498602; called by muse, mutect2, varscan2
- CCDC171 | c.529G>T p.E177* | Nonsense Mutation (SNP) | VAF 9/43 reads (21%) | catalogued as COSV99901270; called by muse, mutect2, varscan2
- CCDC62 | c.37-1G>A p.X13_splice | Splice Site (SNP) | VAF 10/30 reads (33%) | catalogued as COSV99457399; called by muse, mutect2, varscan2
- CD200R1 | c.749T>C p.L250P (on ENST00000471858 / NM_170780.3; = p.L273P on NM_138806.4) | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.945); catalogued as COSV99867508; called by muse, mutect2
- CDC25A | c.373G>A p.D125N | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.995); catalogued as COSV100207574; called by muse, mutect2, varscan2
- CDH6 | c.1339G>A p.D447N | Missense Mutation (SNP) | VAF 39/207 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99419915; called by muse, mutect2, varscan2
- CDK15 | c.976C>A p.P326T (on ENST00000652192 / NM_001366386.2; = p.P275T on NM_139158.2) | Missense Mutation (SNP) | VAF 21/81 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99643417; called by muse, mutect2, varscan2
- CDYL2 | c.721C>T p.R241C | Missense Mutation (SNP) | VAF 49/202 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs756720865, COSV101629580, COSV73654363; called by muse, mutect2, varscan2
- CENPV | c.780G>C p.M260I | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT tolerated (0.18); PolyPhen benign (0.031); catalogued as COSV100233489; called by muse, mutect2, varscan2
- CEP19 | c.366A>T p.E122D | Missense Mutation (SNP) | VAF 19/146 reads (13%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.945); catalogued as COSV99582558; called by muse, mutect2, varscan2
- CEP192 | c.4110G>T p.G1370= | Splice Region (SNP) | VAF 9/72 reads (13%) | catalogued as rs745349077, COSV100381597; called by muse, mutect2, varscan2
- CHD6 | c.7528G>T p.E2510* | Nonsense Mutation (SNP) | VAF 20/103 reads (19%) | catalogued as COSV100951193; called by muse, mutect2, varscan2
- CIB3 | c.410G>T p.R137L | Missense Mutation (SNP) | VAF 25/131 reads (19%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.838); catalogued as rs112299653, COSV54165420, COSV54166004, COSV99521830; called by muse, mutect2, varscan2
- CLCN4 | c.515G>C p.R172P | Missense Mutation (SNP) | VAF 29/101 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.294); catalogued as COSV101073912; called by muse, mutect2, varscan2
- CLCN7 | c.237C>A p.F79L | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT tolerated (0.63); PolyPhen benign (0.015); catalogued as COSV99247437; called by muse, mutect2, varscan2
- CLPX | c.1774G>C p.E592Q | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.023); catalogued as COSV100269560; called by muse, mutect2, varscan2
- CLTCL1 | c.3239C>T p.S1080L | Missense Mutation (SNP) | VAF 18/83 reads (22%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.99); catalogued as COSV99595394; called by muse, mutect2, varscan2
- CLVS1 | c.518C>A p.P173Q | Missense Mutation (SNP) | VAF 63/149 reads (42%) | SIFT tolerated (0.46); PolyPhen benign (0.142); catalogued as COSV100370258; called by muse, mutect2, varscan2
- CMYA5 | c.6167C>T p.S2056L | Missense Mutation (SNP) | VAF 50/145 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); catalogued as COSV71409889; called by muse, mutect2, varscan2
- CNTN4 | c.1757C>G p.S586C | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100639442, COSV61868974; called by muse, mutect2, varscan2
- CNTNAP1 | c.3928C>T p.R1310C | Missense Mutation (SNP) | VAF 24/114 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs948880576, COSV52854005; called by muse, varscan2
- CNTNAP1 | c.3982C>G p.P1328A | Missense Mutation (SNP) | VAF 19/91 reads (21%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0); catalogued as COSV99226698; called by muse, varscan2
- CNTNAP2 | c.178C>A p.P60T | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.133); catalogued as COSV100668236, COSV62171051; called by muse, mutect2, varscan2
- COL2A1 | c.2896-1G>T p.X966_splice | Splice Site (SNP) | VAF 6/28 reads (21%) | catalogued as CS103290, COSV100476944; called by muse, mutect2, varscan2
- COL2A1 | c.349G>A p.G117R | Missense Mutation (SNP) | VAF 8/79 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100476948; called by muse, mutect2, varscan2
- COL4A5 | c.429G>T p.Q143H | Missense Mutation (SNP) | VAF 69/403 reads (17%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.575); catalogued as COSV100088555; called by muse, mutect2, varscan2
- COL6A3 | c.544G>A p.E182K | Missense Mutation (SNP) | VAF 20/86 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0.129); catalogued as COSV55092609, COSV99799695; called by muse, mutect2, varscan2
- CPAMD8 | c.3928-1G>T p.X1310_splice (on ENST00000651564; = p.X1263_splice on NM_015692.5) | Splice Site (SNP) | VAF 17/88 reads (19%) | catalogued as COSV101488540; called by muse, mutect2, varscan2
- CRISP2 | c.417+1G>T p.X139_splice | Splice Site (SNP) | VAF 17/75 reads (23%) | catalogued as COSV100189130; called by muse, mutect2, varscan2
- CSF1R | c.2731C>T p.Q911* | Nonsense Mutation (SNP) | VAF 21/66 reads (32%) | catalogued as rs1187766051, COSV53833640, COSV53839185; called by muse, mutect2, varscan2
- CSMD3 | c.277T>A p.W93R | Missense Mutation (SNP) | VAF 19/131 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99839619; called by muse, mutect2, varscan2
- CUBN | c.9418G>T p.A3140S | Missense Mutation (SNP) | VAF 54/255 reads (21%) | SIFT tolerated (0.27); PolyPhen benign (0.058); catalogued as rs148491916, COSV100913065, COSV64713937; called by muse, mutect2, varscan2
- CUL5 | c.566C>G p.S189C | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.897); catalogued as rs1274019774, COSV101263718, COSV67609117; called by muse, mutect2, varscan2
- CUL7 | c.4319G>A p.R1440Q | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT tolerated (0.68); PolyPhen benign (0.003); catalogued as rs779355111, COSV99538768; called by muse, mutect2, varscan2
- CYHR1 | c.129G>C p.Q43H | Missense Mutation (SNP) | VAF 31/186 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.948); catalogued as COSV100023896; called by muse, mutect2, varscan2
- CYP20A1 | c.116A>T p.E39V | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.332); catalogued as COSV100619084; called by muse, varscan2
- CYP2C18 | c.404G>T p.G135V | Missense Mutation (SNP) | VAF 53/106 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99608716; called by muse, mutect2, varscan2
- DAB1 | c.571G>T p.E191* | Nonsense Mutation (SNP) | VAF 13/139 reads (9%) | catalogued as COSV100140385; called by muse, mutect2
- DAGLA | c.1062C>G p.I354M | Missense Mutation (SNP) | VAF 102/412 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as COSV57197303, COSV99944527; called by muse, mutect2, varscan2
- DDX60 | c.3315G>C p.L1105F | Missense Mutation (SNP) | VAF 13/83 reads (16%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as COSV101190534; called by muse, mutect2, varscan2
- DEFB129 | c.113G>T p.C38F | Missense Mutation (SNP) | VAF 12/77 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99857495; called by muse, mutect2, varscan2
- DGKB | c.368C>G p.S123C | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.161); catalogued as rs186010649, COSV99337433, COSV99341208; called by muse, mutect2, varscan2
- DGLUCY | c.656G>T p.G219V | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as COSV99824494; called by muse, mutect2, varscan2
- DLC1 | c.2798C>G p.S933W (on ENST00000276297 / NM_001348081.2; = p.S496W on NM_006094.5) | Missense Mutation (SNP) | VAF 24/84 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV104370989, COSV99364178; called by muse, mutect2, varscan2
- DNAH7 | c.8738G>T p.G2913V | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100416123; called by muse, mutect2, varscan2
- DNAH9 | c.5830G>A p.D1944N | Missense Mutation (SNP) | VAF 25/92 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV99306770; called by muse, mutect2, varscan2
- DNAJC13 | c.181G>A p.G61R | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT tolerated (0.56); PolyPhen probably damaging (0.997); catalogued as COSV99607626; called by muse, mutect2, varscan2
- DNM3 | c.484C>T p.Q162* | Nonsense Mutation (SNP) | VAF 5/28 reads (18%) | catalogued as COSV100798431; called by muse, mutect2, varscan2
- DOCK1 | c.2140A>G p.K714E | Missense Mutation (SNP) | VAF 44/111 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as COSV99731025; called by muse, mutect2, varscan2
- DOCK11 | c.1524G>T p.K508N | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99354213; called by muse, mutect2, varscan2
- DOCK4 | c.587A>C p.Q196P | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV101455620; called by muse, mutect2
- DPH2 | c.1444G>A p.A482T | Missense Mutation (SNP) | VAF 27/116 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); catalogued as rs760454990, COSV52544672; called by muse, mutect2, varscan2
- DYNC1H1 | c.3748G>T p.V1250L | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT tolerated (0.21); PolyPhen benign (0.255); catalogued as rs369914512, COSV100795105; called by muse, mutect2, varscan2
- DYNC2I1 | c.2360C>G p.S787C | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV68105862; called by mutect2, varscan2
- EDC3 | c.291G>C p.Q97H | Missense Mutation (SNP) | VAF 34/124 reads (27%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.459); catalogued as COSV100166059; called by muse, mutect2, varscan2
- EDEM1 | c.1375C>A p.H459N | Missense Mutation (SNP) | VAF 74/241 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.759); catalogued as rs1303576853, COSV99849310; called by muse, mutect2, varscan2
- EDEM1 | c.1657G>C p.E553Q | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99849311; called by muse, mutect2, varscan2
- EIF4G3 | c.3888C>G p.F1296L | Missense Mutation (SNP) | VAF 19/84 reads (23%) | SIFT tolerated (0.3); PolyPhen benign (0.037); catalogued as COSV99944890; called by muse, mutect2, varscan2
- EML2 | c.655A>T p.T219S | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV99840191; called by muse, mutect2, varscan2
- EMSY | c.2482G>C p.E828Q | Missense Mutation (SNP) | VAF 17/85 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as COSV58259068; called by muse, mutect2, varscan2
- EOLA2 | c.433G>T p.V145L | Missense Mutation (SNP) | VAF 16/113 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100778084; called by muse, mutect2, varscan2
- EPHA4 | c.2644A>T p.I882F | Missense Mutation (SNP) | VAF 50/191 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99917029; called by muse, mutect2, varscan2
- ERAL1 | c.1125G>T p.W375C | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.696); catalogued as COSV99650414; called by muse, mutect2, varscan2
- ERICH3 | c.1529G>T p.G510V | Missense Mutation (SNP) | VAF 25/148 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.031); catalogued as rs757060045, COSV100444956; called by muse, mutect2, varscan2
- ETNPPL | c.1466C>A p.T489K | Missense Mutation (SNP) | VAF 20/105 reads (19%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV99625453; called by muse, mutect2, varscan2
- EVC2 | c.3002C>T p.A1001V | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT tolerated (0.22); PolyPhen benign (0.038); catalogued as rs1238592664, COSV60388197; called by muse, mutect2
- EXOC1 | c.1582G>A p.A528T | Missense Mutation (SNP) | VAF 21/88 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.42); catalogued as COSV100637947; called by muse, mutect2, varscan2
- F8 | c.4021C>G p.L1341V | Missense Mutation (SNP) | VAF 41/202 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV100811660; called by muse, mutect2, varscan2
- F8 | c.362G>C p.G121A | Missense Mutation (SNP) | VAF 58/288 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as CM054673, CM073047, COSV100811661; called by muse, mutect2, varscan2
- FAM133A | c.305G>T p.C102F | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.012); catalogued as COSV100220513, COSV59075757; called by muse, mutect2, varscan2
- FAM13A | c.2449A>C p.S817R | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV99984163; called by muse, mutect2, varscan2
- FAM83A | c.487G>C p.V163L | Missense Mutation (SNP) | VAF 46/301 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as COSV99414396; called by muse, mutect2, varscan2
- FAN1 | c.3042A>C p.Q1014H | Missense Mutation (SNP) | VAF 26/93 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.135); catalogued as COSV100076212; called by muse, mutect2, varscan2
- FAT3 | c.8327G>T p.S2776I | Missense Mutation (SNP) | VAF 19/82 reads (23%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as COSV99967806; called by muse, mutect2, varscan2
- FAT4 | c.12587G>T p.G4196V | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100629253; called by muse, mutect2, varscan2
- FBXW5 | c.568G>C p.D190H | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV99812570; called by muse, mutect2
- FCRL2 | c.364G>T p.G122C | Missense Mutation (SNP) | VAF 13/91 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.886); catalogued as COSV100829954; called by muse, mutect2, varscan2
- FDPS | c.286G>C p.E96Q | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.058); catalogued as COSV100756246, COSV100756305; called by muse, mutect2, varscan2
- FGA | c.1195G>T p.G399C | Missense Mutation (SNP) | VAF 39/192 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV100120526; called by muse, mutect2, varscan2
- FIGN | c.2141C>T p.S714L | Missense Mutation (SNP) | VAF 16/90 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.068); catalogued as COSV100292603; called by muse, mutect2, varscan2
- FKBP4 | c.433G>C p.E145Q | Missense Mutation (SNP) | VAF 7/180 reads (4%) | SIFT tolerated (0.05); PolyPhen benign (0.072); catalogued as COSV99075161; called by muse, mutect2
- FLG | c.4323C>A p.F1441L | Missense Mutation (SNP) | VAF 70/350 reads (20%) | SIFT tolerated (0.65); PolyPhen benign (0.009); catalogued as rs1484882216, COSV100911791; called by muse, mutect2, varscan2
- FLNA | c.3928C>T p.Q1310* | Nonsense Mutation (SNP) | VAF 26/127 reads (20%) | catalogued as COSV61040290; called by muse, mutect2, varscan2
- FLOT1 | c.851G>C p.R284P | Missense Mutation (SNP) | VAF 30/140 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.175); catalogued as COSV100899812; called by muse, mutect2, varscan2
- FMN2 | c.3598C>A p.P1200T | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.38); catalogued as rs1406060384, COSV100146145, COSV60459578; called by muse, mutect2, varscan2
- FREM2 | c.685C>A p.R229S | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.904); catalogued as COSV54827291, COSV99749614; called by muse, mutect2
- FRRS1 | c.705G>C p.M235I | Missense Mutation (SNP) | VAF 21/89 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.396); catalogued as COSV99790060; called by muse, mutect2, varscan2
- GAB4 | c.1045C>A p.L349M | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.396); catalogued as COSV101272026; called by muse, mutect2, varscan2
- GABRG2 | c.70A>T p.T24S | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.138); catalogued as COSV100729766, COSV62717900; called by muse, mutect2, varscan2
- GABRG2 | c.1247C>T p.P416L (on ENST00000361925 / NM_001375343.1; = p.P376L on NM_000816.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as rs1333582494, COSV100729767, COSV62717547; called by muse, mutect2
- GAD1 | c.885G>C p.K295N | Missense Mutation (SNP) | VAF 18/110 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV100713877; called by muse, mutect2, varscan2
- GADL1 | c.908C>G p.S303C | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.029); catalogued as COSV99244670; called by muse, mutect2, varscan2
- GCC2 | c.4678G>C p.E1560Q | Missense Mutation (SNP) | VAF 36/190 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.031); catalogued as COSV100565535; called by muse, mutect2, varscan2
- GFOD2 | c.695dup p.V233Cfs*3 | Frame Shift Ins (INS) | VAF 11/66 reads (17%) | catalogued as rs1567652174; called by mutect2, pindel, varscan2
- GFRAL | c.731G>T p.C244F | Missense Mutation (SNP) | VAF 21/109 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100475483; called by muse, mutect2, varscan2
- GLB1L2 | c.1608C>G p.D536E | Missense Mutation (SNP) | VAF 32/151 reads (21%) | SIFT tolerated (0.59); PolyPhen benign (0.001); catalogued as COSV100335417, COSV100335461, COSV56995580; called by muse, mutect2, varscan2
- GLYR1 | c.1558C>T p.P520S | Missense Mutation (SNP) | VAF 36/172 reads (21%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.78); catalogued as COSV100424382; called by muse, mutect2, varscan2
- GMPR | c.398G>C p.G133A | Missense Mutation (SNP) | VAF 32/162 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as COSV99440315; called by muse, mutect2, varscan2
- GPRC6A | c.103C>A p.H35N | Missense Mutation (SNP) | VAF 22/108 reads (20%) | SIFT tolerated (0.28); PolyPhen benign (0.021); catalogued as COSV59952499; called by muse, mutect2, varscan2
- GPRIN2 | c.953C>T p.S318L | Missense Mutation (SNP) | VAF 8/106 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.74); catalogued as COSV100966431; called by muse, mutect2
- GRIN1 | c.2393G>A p.C798Y | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as COSV100160490; called by muse, mutect2, varscan2
- GRIN2A | c.3785C>G p.T1262S | Missense Mutation (SNP) | VAF 17/92 reads (18%) | SIFT tolerated (0.9); PolyPhen benign (0.003); catalogued as rs587780351, COSV100410409; called by muse, mutect2, varscan2
- GTF3C2 | c.1914C>G p.I638M | Missense Mutation (SNP) | VAF 137/728 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as rs568136490, COSV99273009; called by muse, mutect2, varscan2
- GUCY1A2 | c.508C>G p.Q170E | Missense Mutation (SNP) | VAF 24/79 reads (30%) | SIFT tolerated (0.2); PolyPhen benign (0.138); catalogued as COSV56482801, COSV56485473, COSV99975535; called by muse, mutect2, varscan2
- GXYLT1 | c.945G>T p.W315C | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99788703; called by muse, mutect2, varscan2
- H2BC17 | c.317A>T p.E106V | Missense Mutation (SNP) | VAF 28/109 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.659); catalogued as COSV100377660; called by muse, mutect2, varscan2
- HAO1 | c.643C>A p.P215T | Missense Mutation (SNP) | VAF 22/137 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.062); catalogued as COSV101113252, COSV66494521; called by muse, mutect2, varscan2
- HIBCH | c.126A>T p.K42N | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as COSV100676191; called by muse, mutect2, varscan2
- HPGD | c.427A>G p.M143V | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs758196205, COSV99640488; called by mutect2, varscan2
- HTR2C | c.626T>A p.L209H | Missense Mutation (SNP) | VAF 88/367 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99350015; called by muse, mutect2, varscan2
- HTT | c.2072C>T p.S691L | Missense Mutation (SNP) | VAF 15/84 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as rs779467594, COSV61866792; called by muse, mutect2, varscan2
- ICAM3 | c.1253G>C p.R418T | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as COSV99349155; called by muse, mutect2, varscan2
- ID1 | c.103C>G p.L35V | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.991); catalogued as rs758048335, COSV101076770; called by muse, mutect2, varscan2
- IFI44 | c.658G>T p.V220L | Missense Mutation (SNP) | VAF 26/96 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.044); catalogued as COSV100877366; called by muse, mutect2, varscan2
- IFI44L | c.556A>G p.R186G | Missense Mutation (SNP) | VAF 18/128 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.125); catalogued as COSV60728804; called by muse, mutect2, varscan2
- IGFBP1 | c.408T>A p.D136E | Missense Mutation (SNP) | VAF 27/121 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99298792; called by muse, mutect2, varscan2
- IGHV4-4 | c.14G>T p.W5L | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT tolerated (0.09); PolyPhen benign (0.243); catalogued as rs1555421637; called by muse, mutect2, varscan2
- IL1RAP | c.827C>G p.S276C | Missense Mutation (SNP) | VAF 10/95 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.1); catalogued as COSV99299938; called by muse, mutect2, varscan2
- IL3RA | c.415T>C p.Y139H | Missense Mutation (SNP) | VAF 30/88 reads (34%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.796); catalogued as COSV100452342; called by muse, mutect2, varscan2
- INSR | c.3347G>T p.R1116L | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV100252730; called by muse, mutect2, varscan2
- INTU | c.1294G>T p.D432Y | Missense Mutation (SNP) | VAF 21/125 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV100081069; called by muse, mutect2, varscan2
- IQGAP1 | c.4821C>A p.F1607L | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.222); catalogued as COSV99185170; called by muse, varscan2
- IQSEC2 | c.2029G>A p.G677R (on ENST00000642864 / NM_001111125.3; = p.G472R on NM_015075.2) | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as COSV100944982; called by muse, mutect2, varscan2
- IRAK1 | c.1622C>A p.S541Y | Missense Mutation (SNP) | VAF 14/96 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.769); catalogued as COSV100889019, COSV100889023; called by muse, mutect2, varscan2
- IST1 | c.374C>G p.S125* (on ENST00000535424 / NM_001270976.1; = p.S112* on NM_014761.4) | Nonsense Mutation (SNP) | VAF 20/69 reads (29%) | catalogued as COSV100324763; called by muse, mutect2, varscan2
- ITIH2 | c.2420C>T p.S807L | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.828); catalogued as rs768284181, COSV100623327; called by muse, mutect2
- ITIH6 | c.2341C>G p.P781A | Missense Mutation (SNP) | VAF 24/125 reads (19%) | SIFT tolerated (0.24); PolyPhen benign (0.054); catalogued as COSV99513566; called by muse, mutect2, varscan2
- ITPR3 | c.1409G>T p.R470M | Missense Mutation (SNP) | VAF 14/110 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100967635; called by muse, mutect2, varscan2
- KANSL3 | c.2308G>A p.A770T (on ENST00000666923 / NM_001349262.2; = p.A744T on NM_001115016.3) | Missense Mutation (SNP) | VAF 41/134 reads (31%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.001); catalogued as COSV62616924; called by muse, mutect2, varscan2
- KCNH1 | c.1184G>T p.C395F (on ENST00000271751 / NM_172362.3; = p.C368F on NM_002238.4) | Missense Mutation (SNP) | VAF 28/146 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99660124; called by muse, mutect2, varscan2
- KDM3B | c.1463G>A p.G488E | Missense Mutation (SNP) | VAF 27/86 reads (31%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.025); catalogued as COSV100069924; called by muse, mutect2, varscan2
- KDM3B | c.2244G>C p.E748D | Missense Mutation (SNP) | VAF 63/228 reads (28%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.003); catalogued as COSV100069926; called by muse, mutect2, varscan2
- KIF23 | c.2819G>C p.R940T (on ENST00000260363; = p.R836T on NM_004856.7) | Missense Mutation (SNP) | VAF 16/87 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.1); catalogued as COSV99532508; called by muse, mutect2, varscan2
- KIF4A | c.2311A>G p.R771G | Missense Mutation (SNP) | VAF 17/97 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100790076; called by muse, mutect2, varscan2
- KIF4B | c.2440G>T p.D814Y | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.065); catalogued as COSV101469349; called by muse, mutect2
- KIFC2 | c.664C>G p.R222G | Missense Mutation (SNP) | VAF 26/119 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as COSV100023897; called by muse, mutect2, varscan2
- KIRREL2 | c.80T>C p.L27P | Missense Mutation (SNP) | VAF 36/201 reads (18%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.993); catalogued as COSV99384150; called by muse, mutect2, varscan2
- KLF11 | c.286A>G p.K96E | Missense Mutation (SNP) | VAF 13/87 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100007816; called by muse, mutect2, varscan2
- KLKB1 | c.758G>T p.R253I | Missense Mutation (SNP) | VAF 22/115 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as COSV99250183; called by muse, mutect2, varscan2
- KNG1 | c.803C>A p.P268H | Missense Mutation (SNP) | VAF 24/136 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99405693; called by muse, mutect2, varscan2
- KNTC1 | c.3083C>G p.A1028G | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV100338516; called by muse, varscan2
- KRBA1 | c.1730G>C p.S577T | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.992); catalogued as COSV99752892; called by muse, mutect2, varscan2
- KRTAP10-8 | c.731C>A p.S244Y | Missense Mutation (SNP) | VAF 30/103 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100554502; called by muse, mutect2, varscan2
- LCE2C | c.22C>A p.Q8K | Missense Mutation (SNP) | VAF 27/165 reads (16%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.162); catalogued as COSV100909453; called by muse, mutect2, varscan2
- LCTL | c.1108G>C p.E370Q | Missense Mutation (SNP) | VAF 33/133 reads (25%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.999); catalogued as COSV100328785; called by muse, mutect2, varscan2
- LEPR | c.3251C>G p.S1084* | Nonsense Mutation (SNP) | VAF 17/93 reads (18%) | catalogued as COSV100848376; called by muse, mutect2, varscan2
- LEPROT | c.61C>G p.L21V | Missense Mutation (SNP) | VAF 32/97 reads (33%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.997); catalogued as COSV100756669; called by muse, mutect2, varscan2
- LRRC4C | c.1282G>T p.V428L | Missense Mutation (SNP) | VAF 36/190 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.791); catalogued as COSV99538862, COSV99540036; called by muse, mutect2, varscan2
- LRRCC1 | c.2480G>C p.R827T | Missense Mutation (SNP) | VAF 25/134 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.556); catalogued as rs1482989472, COSV100835503, COSV64483505; called by muse, mutect2, varscan2
- MALT1 | c.1564G>C p.D522H | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV100618796; called by muse, mutect2, varscan2
- MAMLD1 | c.1076C>T p.P359L | Missense Mutation (SNP) | VAF 31/137 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.382); catalogued as COSV53379552, COSV99476267; called by muse, mutect2, varscan2
- MAN1A2 | c.1870C>G p.L624V | Missense Mutation (SNP) | VAF 18/120 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.817); catalogued as COSV100740997; called by muse, mutect2, varscan2
- MAP1B | c.5800G>A p.E1934K | Missense Mutation (SNP) | VAF 33/261 reads (13%) | SIFT tolerated (0.29); PolyPhen benign (0.112); catalogued as rs1182128277, COSV99702634; called by muse, mutect2, varscan2
- MAP3K1 | c.3877G>C p.E1293Q | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.788); catalogued as COSV101267029; called by muse, mutect2, varscan2
- MARK4 | c.904G>T p.E302* | Nonsense Mutation (SNP) | VAF 21/99 reads (21%) | catalogued as COSV99488496; called by muse, mutect2, varscan2
- MC5R | c.826C>G p.H276D | Missense Mutation (SNP) | VAF 49/145 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.751); catalogued as COSV100229098; called by muse, mutect2, varscan2
- MDN1 | c.16496G>A p.R5499Q | Missense Mutation (SNP) | VAF 22/99 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1466064330, COSV65519801; called by muse, mutect2, varscan2
- MECP2 | c.764G>A p.R255Q | Missense Mutation (SNP) | VAF 49/206 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV100318247; called by muse, mutect2, varscan2
- MED1 | c.3523C>G p.Q1175E | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.22); catalogued as COSV100327961, COSV56125854; called by muse, mutect2, varscan2
- MED1 | c.3428C>G p.S1143C | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.012); catalogued as COSV100327962; called by muse, mutect2, varscan2
- MEF2C | c.520C>T p.H174Y | Missense Mutation (SNP) | VAF 61/207 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV60925254; called by muse, mutect2, varscan2
- MINAR1 | c.1719C>A p.N573K | Missense Mutation (SNP) | VAF 20/95 reads (21%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as COSV100549039, COSV59584670; called by muse, mutect2, varscan2
- MINDY4 | c.562G>T p.E188* | Nonsense Mutation (SNP) | VAF 16/105 reads (15%) | catalogued as COSV99518989; called by muse, mutect2, varscan2
- MIP | c.760G>T p.E254* | Nonsense Mutation (SNP) | VAF 19/89 reads (21%) | catalogued as COSV99234334; called by muse, mutect2, varscan2
- MKRN2 | c.884C>G p.S295* | Nonsense Mutation (SNP) | VAF 26/86 reads (30%) | catalogued as COSV99403294; called by muse, mutect2, varscan2
- MKRN3 | c.1089G>T p.Q363H | Missense Mutation (SNP) | VAF 27/88 reads (31%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.551); catalogued as COSV100091352; called by muse, mutect2, varscan2
- MRM3 | c.523G>C p.D175H | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.726); catalogued as COSV100022665; called by muse, mutect2, varscan2
- MTSS1 | c.1231G>A p.D411N | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as rs140769162; called by muse, mutect2, varscan2
- MUC16 | c.22580C>G p.S7527C | Missense Mutation (SNP) | VAF 13/89 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.85); catalogued as COSV67442524, COSV67459123; called by muse, mutect2, varscan2
- MUC16 | c.144C>G p.I48M | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.606); catalogued as COSV101200432, COSV67442499; called by muse, mutect2, varscan2
- MUC3A | c.7540A>C p.T2514P | Missense Mutation (SNP) | VAF 27/151 reads (18%) | SIFT deleterious, low confidence (0.04); catalogued as COSV100114930; called by muse, mutect2, varscan2
- MYB | c.1480C>G p.L494V | Missense Mutation (SNP) | VAF 30/114 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.118); catalogued as COSV100215000; called by muse, mutect2, varscan2
- MYO1A | c.2767C>G p.L923V | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.125); catalogued as COSV100271075; called by muse, mutect2, varscan2
- MYOM2 | c.4020G>C p.E1340D | Missense Mutation (SNP) | VAF 30/113 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.927); catalogued as rs758543224, COSV100037874; called by muse, mutect2, varscan2
- MYOM3 | c.3004A>T p.R1002* | Nonsense Mutation (SNP) | VAF 14/77 reads (18%) | catalogued as COSV100293223; called by muse, mutect2, varscan2
- NCAN | c.1835C>T p.S612L | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs754950280, COSV53051608; called by muse, mutect2, varscan2
- NEXMIF | c.3774G>T p.L1258F | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); catalogued as COSV50032479, COSV99281226; called by muse, mutect2, varscan2
- NF1 | c.1198C>T p.Q400* | Nonsense Mutation (SNP) | VAF 26/113 reads (23%) | catalogued as CM1311454, COSV62224610; called by muse, mutect2, varscan2
- NHLH1 | c.94C>A p.P32T | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.023); catalogued as COSV100131563; called by muse, mutect2
- NLRP1 | c.1470C>G p.F490L | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.615); catalogued as COSV52566181, COSV99334742; called by muse, mutect2, varscan2
- NLRP13 | c.2608G>C p.E870Q | Missense Mutation (SNP) | VAF 21/89 reads (24%) | SIFT tolerated (0.96); PolyPhen benign (0.05); catalogued as rs749274906, COSV100738358; called by muse, mutect2, varscan2
- NOG | c.166C>T p.P56S | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100240620; called by muse, mutect2, varscan2
- NOX1 | c.1525A>T p.M509L | Missense Mutation (SNP) | VAF 34/200 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.026); catalogued as COSV99471645; called by muse, mutect2, varscan2
- NUP133 | c.2734G>T p.G912C | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99773164; called by muse, mutect2, varscan2
- ODF2 | c.26C>A p.S9Y | Missense Mutation (SNP) | VAF 24/162 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.919); catalogued as COSV100654794; called by muse, mutect2, varscan2
- OR1M1 | c.374C>A p.A125D | Missense Mutation (SNP) | VAF 22/115 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1396295342, COSV101447573, COSV70036387; called by muse, varscan2
- OR2A14 | c.106C>T p.L36F | Missense Mutation (SNP) | VAF 24/148 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs571073012, COSV101376477; called by muse, mutect2, varscan2
- OR4C12 | c.457C>T p.H153Y | Missense Mutation (SNP) | VAF 51/261 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs267602935, COSV100078248; called by muse, mutect2, varscan2
- OR4C15 | c.274G>T p.G92W (on ENST00000314644; = p.G38W on NM_001001920.2) | Missense Mutation (SNP) | VAF 27/183 reads (15%) | SIFT tolerated, low confidence (0.2); PolyPhen probably damaging (1); catalogued as COSV100115845; called by muse, mutect2, varscan2
- OR51F1 | c.515T>A p.L172H | Missense Mutation (SNP) | VAF 25/92 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV100598833; called by muse, mutect2, varscan2
- OR5AS1 | c.850A>T p.M284L | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.924); catalogued as COSV57981934; called by muse, mutect2, varscan2
- OR5W2 | c.293C>A p.A98D | Missense Mutation (SNP) | VAF 22/125 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.714); catalogued as COSV100747557; called by muse, mutect2, varscan2
- ORC1 | c.1262G>T p.S421I | Missense Mutation (SNP) | VAF 33/173 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.216); catalogued as COSV100856708; called by muse, mutect2, varscan2
- PALLD | c.187G>C p.E63Q | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.446); catalogued as COSV99825218; called by muse, mutect2, varscan2
- PARPBP | c.527C>T p.S176L | Missense Mutation (SNP) | VAF 25/120 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as COSV59672574; called by muse, mutect2, varscan2
- PCDH19 | c.2611C>A p.P871T (on ENST00000373034 / NM_001184880.2; = p.P824T on NM_020766.3) | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.996); catalogued as COSV99720262; called by muse, mutect2, varscan2
- PCDHGA12 | c.610G>C p.E204Q | Missense Mutation (SNP) | VAF 33/153 reads (22%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.271); catalogued as COSV99341204; called by muse, mutect2, varscan2
- PCDHGA6 | c.1676C>G p.A559G | Missense Mutation (SNP) | VAF 68/254 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.535); catalogued as COSV99541977; called by muse, mutect2, varscan2
- PDE6G | c.56G>A p.G19E | Missense Mutation (SNP) | VAF 40/162 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV100148593; called by muse, mutect2, varscan2
- PHC1 | c.1966G>T p.G656C | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.112); catalogued as COSV101418661; called by muse, mutect2, varscan2
- PHC1 | c.1967G>T p.G656V | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV101418663; called by muse, mutect2, varscan2
- PIGL | c.373G>C p.E125Q | Missense Mutation (SNP) | VAF 40/131 reads (31%) | SIFT tolerated (0.56); PolyPhen benign (0.007); catalogued as COSV99848728; called by muse, mutect2, varscan2
- PIK3C3 | c.1016G>T p.W339L | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV100011224; called by muse, mutect2, varscan2
- PIP5K1C | c.1961A>G p.Y654C | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT tolerated, low confidence (0.15); PolyPhen possibly damaging (0.594); catalogued as rs771346345, COSV100095691; called by muse, mutect2, varscan2
- PKHD1 | c.1019G>T p.G340V | Missense Mutation (SNP) | VAF 28/181 reads (15%) | SIFT tolerated (0.32); PolyPhen benign (0.299); catalogued as COSV100583720; called by muse, mutect2, varscan2
- PLA2G6 | c.1828G>A p.E610K | Missense Mutation (SNP) | VAF 18/105 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.223); catalogued as COSV100140566; called by muse, mutect2, varscan2
- PLEC | c.9970G>A p.G3324R (on ENST00000322810 / NM_201380.4; = p.G3214R on NM_000445.5) | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs1554681164, COSV100516034, COSV59639435; called by muse, mutect2, varscan2
- PLEC | c.7558G>C p.E2520Q (on ENST00000322810 / NM_201380.4; = p.E2410Q on NM_000445.5) | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.82); catalogued as COSV100516041, COSV100518327; called by muse, mutect2
- PLEKHF2 | c.41G>C p.R14P | Missense Mutation (SNP) | VAF 48/107 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59540941, COSV59541236; called by muse, mutect2, varscan2
- PLEKHG4 | c.2123G>A p.G708E | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.476); catalogued as COSV100431071; called by muse, mutect2, varscan2
- PLPP5 | c.147C>G p.Y49* | Nonsense Mutation (SNP) | VAF 9/28 reads (32%) | catalogued as COSV100395453; called by muse, mutect2, varscan2
- PNISR | c.1281G>A p.W427* | Nonsense Mutation (SNP) | VAF 18/153 reads (12%) | catalogued as COSV65079084; called by muse, mutect2, varscan2
- POF1B | c.334C>A p.H112N | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.037); catalogued as COSV99427003; called by muse, mutect2, varscan2
- POLDIP2 | c.161G>T p.R54L | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.726); catalogued as COSV50228117, COSV99134829; called by muse, mutect2
- POLR3E | c.256G>C p.A86P | Missense Mutation (SNP) | VAF 21/89 reads (24%) | SIFT tolerated (0.3); PolyPhen benign (0.22); catalogued as COSV100242244; called by muse, mutect2, varscan2
- PPFIBP1 | c.905-1G>C p.X302_splice (on ENST00000318304 / NM_177444.3; = p.X282_splice on NM_003622.4) | Splice Site (SNP) | VAF 10/51 reads (20%) | catalogued as COSV99945102; called by muse, mutect2, varscan2
- PPP1R3A | c.1159G>A p.D387N | Missense Mutation (SNP) | VAF 39/192 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.343); catalogued as rs772888498, COSV99493411; called by muse, mutect2, varscan2
- PRB4 | c.223C>G p.P75A | Missense Mutation (SNP) | VAF 109/941 reads (12%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.97); catalogued as COSV54397353, COSV54397688, COSV99686683; called by muse, varscan2
- PRDM2 | c.3778G>C p.E1260Q | Missense Mutation (SNP) | VAF 49/194 reads (25%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.622); catalogued as COSV99342186; called by muse, mutect2, varscan2
- PRIM1 | c.807G>C p.W269C | Missense Mutation (SNP) | VAF 50/340 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100590430; called by muse, mutect2, varscan2
- PRKG2 | c.1340C>T p.S447L | Missense Mutation (SNP) | VAF 49/232 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.065); catalogued as COSV100020129; called by muse, mutect2, varscan2
- PROK2 | c.103G>A p.D35N | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.465); catalogued as COSV99817005; called by muse, mutect2, varscan2
- PRPF6 | c.317C>T p.A106V | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.288); catalogued as COSV99412352; called by muse, mutect2, varscan2
- PRR14 | c.1588C>T p.R530* | Nonsense Mutation (SNP) | VAF 35/172 reads (20%) | catalogued as rs1334805126, COSV54914040; called by muse, mutect2, varscan2
- PSKH1 | c.230C>T p.P77L | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as rs1230609617, COSV99344805; called by muse, mutect2, varscan2
- PTPN13 | c.5455C>A p.Q1819K (on ENST00000411767 / NM_080683.3; = p.Q1800K on NM_006264.3) | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100365082; called by muse, mutect2, varscan2
- PTPRE | c.728A>G p.K243R | Missense Mutation (SNP) | VAF 64/119 reads (54%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.686); catalogued as COSV99618356; called by muse, mutect2, varscan2
- PYCR1 | c.902C>T p.S301L | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as rs373840170; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RAB11A | c.357C>G p.I119M | Missense Mutation (SNP) | VAF 51/213 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.588); catalogued as COSV99976761; called by muse, mutect2, varscan2
- RAB39A | c.575G>A p.G192E | Missense Mutation (SNP) | VAF 13/82 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100269235; called by muse, mutect2, varscan2
- RAB41 | c.607G>A p.E203K (on ENST00000374473 / NM_001363807.1; = p.E202K on NM_001032726.3) | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.031); catalogued as rs1205720440, COSV99333761; called by muse, varscan2
- RACK1 | c.114G>C p.K38N | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.305); catalogued as COSV100958766; called by muse, mutect2, varscan2
- RAN | c.418C>T p.R140* | Nonsense Mutation (SNP) | VAF 11/80 reads (14%) | catalogued as COSV54563341; called by muse, mutect2, varscan2
- RBM47 | c.151G>T p.G51W | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs777636369, COSV55932321; called by muse, mutect2, varscan2
- RBMX2 | c.346C>G p.R116G | Missense Mutation (SNP) | VAF 28/171 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.162); catalogued as COSV100564812, COSV59729244; called by muse, mutect2, varscan2
- RELN | c.3765G>T p.W1255C | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100634191; called by muse, mutect2, varscan2
- REXO5 | c.262C>T p.L88F | Missense Mutation (SNP) | VAF 22/79 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.359); catalogued as COSV99759315; called by muse, mutect2, varscan2
- RFC2 | c.745G>C p.E249Q (on ENST00000055077 / NM_181471.3; = p.E215Q on NM_002914.4) | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.063); catalogued as COSV99277787; called by muse, mutect2, varscan2
- RGS11 | c.1110C>A p.D370E (on ENST00000397770 / NM_183337.3; = p.D349E on NM_003834.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.568); catalogued as COSV99395883; called by muse, mutect2, varscan2
- RHOQ | c.16G>T p.G6C | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.006); catalogued as COSV99475862; called by muse, mutect2, varscan2
- RICTOR | c.418G>A p.E140K | Missense Mutation (SNP) | VAF 21/188 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.906); catalogued as COSV57129611; called by muse, mutect2, varscan2
- RNASE10 | c.160G>C p.E54Q | Missense Mutation (SNP) | VAF 40/142 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.36); catalogued as COSV100116180; called by muse, mutect2, varscan2
- RPGRIP1 | c.2187G>T p.E729D | Missense Mutation (SNP) | VAF 26/101 reads (26%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.915); catalogued as COSV99251349; called by muse, mutect2, varscan2
- RPRD2 | c.2644G>A p.E882K | Missense Mutation (SNP) | VAF 39/161 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV100955190; called by muse, mutect2, varscan2
- RSPH3 | c.749G>C p.R250T (on ENST00000252655; = p.R108T on NM_031924.8) | Missense Mutation (SNP) | VAF 43/277 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51924480; called by muse, mutect2, varscan2
- RSPH3 | c.350C>G p.S117C | Missense Mutation (SNP) | VAF 20/185 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.015); catalogued as COSV99396448; called by muse, mutect2, varscan2
- RTL9 | c.2006C>T p.S669L | Missense Mutation (SNP) | VAF 19/99 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs148619359, COSV101511787, COSV71825504; called by muse, mutect2, varscan2
- RTTN | c.4792C>G p.L1598V | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT tolerated (0.44); PolyPhen benign (0.079); catalogued as COSV99733038; called by muse, mutect2, varscan2
- RYR2 | c.6772C>A p.R2258S | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.799); catalogued as COSV100767052, COSV63660486, COSV63705121; called by muse, mutect2
- RYR2 | c.14494G>A p.E4832K | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1443988544, COSV63658068; called by muse, mutect2, varscan2
- RYR3 | c.9814G>C p.V3272L (on ENST00000389232; = p.V3273L on NM_001036.6) | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as COSV101211962, COSV101213184; called by muse, mutect2, varscan2
- SAT2 | c.63T>G p.I21M | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.255); catalogued as rs1328421282, COSV99352261; called by muse, mutect2, varscan2
- SCN2A | c.1611C>A p.F537L | Missense Mutation (SNP) | VAF 30/133 reads (23%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.714); catalogued as COSV99332415; called by muse, mutect2, varscan2
- SCN9A | c.3424G>C p.E1142Q (on ENST00000303354; = p.E1131Q on NM_002977.3) | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.598); catalogued as COSV100313442, COSV57613384; called by muse, mutect2
- SCRIB | c.2510G>A p.R837Q | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.701); catalogued as rs781975963, COSV100253703; called by muse, varscan2
- SEC24B | c.1135G>T p.E379* | Nonsense Mutation (SNP) | VAF 45/157 reads (29%) | catalogued as COSV99493900; called by muse, mutect2, varscan2
- SETD1A | c.4301G>T p.G1434V | Missense Mutation (SNP) | VAF 20/88 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as COSV99353346; called by muse, mutect2, varscan2
- SF3B3 | c.2114G>T p.R705L | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as COSV100210050; called by muse, mutect2, varscan2
- SGCZ | c.75G>T p.Q25H | Missense Mutation (SNP) | VAF 44/189 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.443); catalogued as rs754438054, COSV66015257; called by muse, mutect2, varscan2
- SIRPG | c.704G>A p.G235E | Missense Mutation (SNP) | VAF 21/84 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.37); catalogued as COSV53805879; called by muse, mutect2, varscan2
- SIRT7 | c.450G>A p.M150I | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as COSV100155618; called by muse, mutect2, varscan2
- SLAIN2 | c.911C>T p.S304L | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); catalogued as COSV99971743; called by muse, mutect2, varscan2
- SLC25A28 | c.803G>C p.G268A | Missense Mutation (SNP) | VAF 20/77 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100979621; called by muse, mutect2, varscan2
- SLC25A42 | c.65C>T p.S22L | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as rs748394350, COSV100588141; called by muse, mutect2, varscan2
- SLC26A5 | c.1623T>G p.N541K | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as COSV100099713; called by muse, mutect2, varscan2
- SLC2A2 | c.1102C>G p.L368V | Missense Mutation (SNP) | VAF 30/210 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as COSV100049419, COSV58586879, COSV58587380; called by muse, varscan2
- SLC43A1 | c.1559C>G p.S520* | Nonsense Mutation (SNP) | VAF 6/23 reads (26%) | catalogued as COSV99561100; called by mutect2, varscan2
- SLC4A4 | c.2999G>T p.S1000I (on ENST00000264485 / NM_001098484.3; = p.S956I on NM_003759.4) | Missense Mutation (SNP) | VAF 27/102 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.323); catalogued as COSV99140698; called by muse, mutect2, varscan2
- SLC6A19 | c.1511C>T p.S504F | Missense Mutation (SNP) | VAF 18/98 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); catalogued as rs757533736, COSV100443601, COSV100443702; called by muse, mutect2, varscan2
- SLITRK3 | c.435C>A p.F145L | Missense Mutation (SNP) | VAF 9/84 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV99579595; called by muse, mutect2, varscan2
- SMAP2 | c.1228T>G p.S410A | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT tolerated (0.28); PolyPhen benign (0.024); catalogued as COSV101019142; called by muse, varscan2
- SMAP2 | c.1229C>G p.S410* | Nonsense Mutation (SNP) | VAF 14/85 reads (16%) | catalogued as COSV101019145; called by muse, varscan2
- SMG9 | c.49C>T p.R17W | Missense Mutation (SNP) | VAF 10/178 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as rs374528302; called by muse, mutect2
- SNX5 | c.831+1G>T p.X277_splice | Splice Site (SNP) | VAF 22/121 reads (18%) | catalogued as COSV100899031; called by muse, mutect2, varscan2
- SOCS6 | c.142G>T p.G48C | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.781); catalogued as COSV101205798; called by muse, mutect2, varscan2
- SOX8 | c.548A>G p.H183R | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV99559316; called by muse, mutect2, varscan2
- SPAG17 | c.6464C>T p.S2155L | Missense Mutation (SNP) | VAF 23/153 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs777946969, COSV100309669; called by muse, mutect2, varscan2
- SPAG9 | c.1608G>T p.R536= (on ENST00000262013 / NM_001130528.3; = p.R522= on NM_003971.6) | Splice Region (SNP) | VAF 6/36 reads (17%) | catalogued as COSV56246418; called by muse, mutect2, varscan2
- SPEN | c.5044G>C p.E1682Q | Missense Mutation (SNP) | VAF 52/219 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.094); catalogued as COSV101005393; called by muse, mutect2, varscan2
- SPEN | c.6373G>A p.E2125K | Missense Mutation (SNP) | VAF 40/195 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV101005395; called by muse, mutect2
- SPEN | c.6732G>C p.Q2244H | Missense Mutation (SNP) | VAF 33/161 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.459); catalogued as COSV101005397; called by muse, mutect2, varscan2
- SPEN | c.6898G>T p.E2300* | Nonsense Mutation (SNP) | VAF 36/166 reads (22%) | catalogued as COSV101005398; called by muse, mutect2, varscan2
- SPEN | c.7059G>C p.E2353D | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.003); catalogued as COSV101005399; called by muse, varscan2
- SPEN | c.7158G>C p.Q2386H | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.459); catalogued as COSV65357721; called by muse, varscan2
- SPTBN4 | c.2974C>A p.H992N | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.388); catalogued as COSV100151467; called by muse, mutect2, varscan2
- SRGAP1 | c.676C>A p.Q226K | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.045); catalogued as COSV100754888; called by muse, mutect2, varscan2
- SRPK1 | c.922G>C p.E308Q | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.205); catalogued as COSV100644386; called by muse, mutect2
- SRRM2 | c.2878G>A p.E960K | Missense Mutation (SNP) | VAF 33/187 reads (18%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0); catalogued as COSV100071085; called by muse, mutect2, varscan2
- SSH2 | c.793A>C p.K265Q | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.355); catalogued as COSV99282500; called by muse, mutect2, varscan2
- STAG2 | c.1116G>T p.K372N | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV99494322; called by muse, mutect2, varscan2
- STAG2 | c.1116+1G>T p.X372_splice | Splice Site (SNP) | VAF 13/48 reads (27%) | catalogued as COSV99494325; called by muse, mutect2, varscan2
- SURF2 | c.433C>T p.R145C | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT tolerated (0.18); PolyPhen benign (0.02); catalogued as rs1182952634, COSV64332277, COSV64332613; called by muse, mutect2, varscan2
- SYCP1 | c.802-1G>T p.X268_splice | Splice Site (SNP) | VAF 10/40 reads (25%) | catalogued as COSV101051022; called by muse, mutect2
- SYNE1 | c.15255G>C p.M5085I (on ENST00000367255 / NM_182961.4; = p.M5014I on NM_033071.3) | Missense Mutation (SNP) | VAF 19/86 reads (22%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV99571195; called by muse, mutect2, varscan2
- SYNE1 | c.12964G>C p.E4322Q (on ENST00000367255 / NM_182961.4; = p.E4251Q on NM_033071.3) | Missense Mutation (SNP) | VAF 21/129 reads (16%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as COSV99571200; called by muse, mutect2, varscan2
- TAC4 | c.322G>A p.E108K | Missense Mutation (SNP) | VAF 25/100 reads (25%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.112); catalogued as COSV100402799; called by muse, mutect2, varscan2
- TAF1L | c.1138G>A p.G380R | Missense Mutation (SNP) | VAF 43/195 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.729); catalogued as COSV99644765; called by muse, mutect2, varscan2
- TBC1D19 | c.535A>G p.R179G | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as COSV99336595; called by muse, mutect2
- TCF7L1 | c.1688C>T p.P563L | Missense Mutation (SNP) | VAF 26/112 reads (23%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.031); catalogued as COSV99964542; called by muse, mutect2, varscan2
- TENM1 | c.218-1G>C p.X73_splice | Splice Site (SNP) | VAF 37/166 reads (22%) | catalogued as COSV100950410, COSV100950653; called by muse, mutect2, varscan2
- TENM4 | c.2787G>A p.M929I | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV99576407; called by muse, mutect2, varscan2
- TEX15 | c.5989G>C p.E1997Q (on ENST00000256246; = p.E2380Q on NM_001350162.2) | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.64); catalogued as COSV99821725; called by muse, mutect2, varscan2
- TEX19 | c.418G>A p.D140N | Missense Mutation (SNP) | VAF 38/152 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.029); catalogued as COSV100331054; called by muse, varscan2
- THBS2 | c.3325G>A p.A1109T | Missense Mutation (SNP) | VAF 17/117 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV100827972; called by muse, mutect2, varscan2
- THSD7B | c.4657G>T p.D1553Y (on ENST00000272643; = p.D1551Y on NM_001316349.2) | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV99754192; called by muse, mutect2
- TMCO4 | c.284G>A p.G95E | Missense Mutation (SNP) | VAF 27/102 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.197); catalogued as rs781545231, COSV99617044; called by muse, mutect2, varscan2
- TMEM185A | c.335G>T p.W112L | Missense Mutation (SNP) | VAF 38/199 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100383098; called by muse, mutect2, varscan2
- TMEM37 | c.542A>T p.H181L | Missense Mutation (SNP) | VAF 79/344 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as COSV99191647; called by muse, mutect2, varscan2
- TMEM74 | c.185C>T p.S62F | Missense Mutation (SNP) | VAF 28/165 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.021); catalogued as rs570860881, COSV52462979, COSV99865765; called by muse, mutect2, varscan2
- TMTC1 | c.2524G>T p.A842S (on ENST00000539277 / NM_001193451.2; = p.A734S on NM_175861.3) | Missense Mutation (SNP) | VAF 25/163 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.571); catalogued as COSV99760231; called by muse, mutect2, varscan2
- TNPO3 | c.1459G>C p.E487Q | Missense Mutation (SNP) | VAF 27/100 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.959); catalogued as COSV99603175; called by muse, mutect2, varscan2
- TOPBP1 | c.1668G>C p.K556N | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99605539; called by muse, varscan2
- TOX2 | c.853G>C p.V285L (on ENST00000358131 / NM_001098798.2; = p.V234L on NM_032883.3) | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1462680382, COSV100364157, COSV57882743; called by muse, mutect2, varscan2
- TPO | c.2225G>A p.C742Y | Missense Mutation (SNP) | VAF 27/138 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100221613; called by muse, mutect2, varscan2
- TRAFD1 | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 39/144 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.96); catalogued as COSV57505416, COSV99986927; called by muse, mutect2, varscan2
- TRERF1 | c.2557T>A p.F853I | Missense Mutation (SNP) | VAF 24/106 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.795); catalogued as COSV100551091; called by muse, mutect2, varscan2
- TRIM39 | c.763G>T p.G255C | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.94); catalogued as COSV100935856; called by muse, mutect2, varscan2
- TRO | c.1676T>A p.L559Q | Missense Mutation (SNP) | VAF 44/210 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99436862; called by muse, mutect2, varscan2
- TRPC4 | c.574C>T p.H192Y | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV100157263; called by muse, mutect2, varscan2
- TRRAP | c.5242C>G p.Q1748E (on ENST00000359863 / NM_001244580.1; = p.Q1730E on NM_003496.3) | Missense Mutation (SNP) | VAF 34/116 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.039); catalogued as rs781888565, COSV100722668; called by muse, mutect2, varscan2
- TTC16 | c.1211G>T p.R404L | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.186); catalogued as COSV100959920; called by muse, mutect2, varscan2
- TTC6 | c.1312G>T p.D438Y (on ENST00000267368; = p.D1804Y on NM_001310135.3) | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99942046; called by muse, mutect2, varscan2
- TTI1 | c.2143A>G p.T715A | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100989662; called by muse, mutect2, varscan2
- TTLL1 | c.586G>C p.D196H | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.924); catalogued as rs1326046656, COSV99840450; called by muse, mutect2, varscan2
- TTN | c.92231C>A p.T30744N (on ENST00000591111; = p.T23320N on NM_003319.4) | Missense Mutation (SNP) | VAF 35/190 reads (18%) | PolyPhen possibly damaging (0.545); catalogued as COSV100620363; called by muse, mutect2, varscan2
- TTN | c.25174G>A p.D8392N (on ENST00000591111; = p.D7465N on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 61/284 reads (21%) | PolyPhen probably damaging (0.999); catalogued as COSV100605833, COSV59875841; called by muse, mutect2, varscan2
- TUT4 | c.4264G>A p.E1422K | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.02); catalogued as COSV99932557; called by muse, mutect2
- UBR1 | c.10G>A p.E4K | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.039); catalogued as COSV51931151; called by muse, mutect2, varscan2
- UNC13B | c.1237A>T p.I413F | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101036922; called by muse, mutect2
- USH2A | c.9314C>G p.T3105S | Missense Mutation (SNP) | VAF 35/198 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV100238311, COSV56443713; called by muse, mutect2, varscan2
- USH2A | c.8629C>A p.H2877N | Missense Mutation (SNP) | VAF 66/271 reads (24%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.494); catalogued as COSV100238315; called by muse, mutect2, varscan2
- USP26 | c.1285G>T p.G429W | Missense Mutation (SNP) | VAF 30/158 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.932); catalogued as COSV100896686; called by muse, mutect2, varscan2
- VIP | c.439T>A p.L147M | Missense Mutation (SNP) | VAF 30/108 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100923948; called by muse, mutect2, varscan2
- VPS13D | c.7939G>C p.E2647Q | Missense Mutation (SNP) | VAF 46/175 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0.231); catalogued as rs1180874967, COSV99167487, COSV99169351; called by muse, mutect2, varscan2
- WDR18 | c.1298G>C p.*433Sext*12 | Nonstop Mutation (SNP) | VAF 4/21 reads (19%) | catalogued as COSV99242933; called by muse, mutect2, varscan2
- WDR26 | c.1097G>T p.R366L (on ENST00000414423 / NM_001379403.1; = p.R266L on NM_025160.7) | Missense Mutation (SNP) | VAF 15/80 reads (19%) | SIFT tolerated (0.53); PolyPhen benign (0.075); catalogued as COSV54359743, COSV99691342; called by muse, mutect2, varscan2
- WNT8A | c.932G>T p.S311I | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100843066; called by muse, mutect2, varscan2
- XKR4 | c.846G>C p.Q282H | Missense Mutation (SNP) | VAF 23/144 reads (16%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.452); catalogued as COSV100533189, COSV59308474; called by muse, mutect2, varscan2
- YAP1 | c.951G>T p.R317S (on ENST00000282441 / NM_001130145.3; = p.R279S on NM_006106.5) | Missense Mutation (SNP) | VAF 16/102 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV99176232; called by muse, mutect2, varscan2
- YEATS2 | c.1245G>C p.Q415H | Missense Mutation (SNP) | VAF 44/277 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.804); catalogued as COSV100528053; called by muse, mutect2, varscan2
- YTHDF1 | c.1166G>T p.G389V | Missense Mutation (SNP) | VAF 30/175 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.983); catalogued as COSV64832765; called by muse, mutect2, varscan2
- ZBTB33 | c.1036C>A p.P346T | Missense Mutation (SNP) | VAF 54/222 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.3); catalogued as COSV100434228, COSV100434285; called by muse, mutect2, varscan2
- ZBTB49 | c.1642G>T p.G548C | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.558); catalogued as COSV100552524; called by muse, mutect2, varscan2
- ZDHHC7 | c.373C>G p.P125A | Missense Mutation (SNP) | VAF 28/176 reads (16%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.574); catalogued as COSV100568923, COSV58214055; called by muse, mutect2, varscan2
- ZEB2 | c.1390C>A p.L464I | Missense Mutation (SNP) | VAF 18/106 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100356437; called by muse, mutect2, varscan2
- ZIC1 | c.589T>C p.Y197H | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.947); catalogued as COSV99292122; called by muse, mutect2, varscan2
- ZMYND8 | c.974C>G p.S325C (on ENST00000311275 / NM_001363741.2; = p.S345C on NM_012408.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/110 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV99520901; called by muse, mutect2, varscan2
- ZNF17 | c.1733G>T p.R578M | Missense Mutation (SNP) | VAF 32/88 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.14); catalogued as COSV100300101; called by muse, mutect2, varscan2
- ZNF184 | c.203G>C p.G68A | Missense Mutation (SNP) | VAF 21/81 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.115); catalogued as COSV99279830; called by muse, mutect2, varscan2
- ZNF253 | c.1084C>T p.H362Y | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV63037253; called by muse, mutect2, varscan2
- ZNF28 | c.493G>A p.E165K | Missense Mutation (SNP) | VAF 49/392 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.098); catalogued as COSV60423377; called by muse, mutect2, varscan2
- ZNF283 | c.540C>G p.I180M | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV100190799; called by muse, mutect2, varscan2
- ZNF318 | c.1159G>C p.E387Q | Missense Mutation (SNP) | VAF 15/106 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs747981377, COSV100546353; called by muse, mutect2, varscan2
- ZNF532 | c.1633A>T p.T545S | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT tolerated (0.74); PolyPhen benign (0.025); catalogued as COSV100266842; called by muse, mutect2, varscan2
- ZNF549 | c.1773G>C p.E591D (on ENST00000376233 / NM_001199295.2; = p.E578D on NM_153263.2) | Missense Mutation (SNP) | VAF 16/114 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.078); catalogued as COSV99558660; called by muse, mutect2, varscan2
- ZNF551 | c.1730A>T p.H577L | Missense Mutation (SNP) | VAF 22/186 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV56593221, COSV99990093; called by muse, mutect2, varscan2
- ZNF552 | c.454G>C p.E152Q | Missense Mutation (SNP) | VAF 28/224 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.042); catalogued as COSV101197519, COSV101197545; called by muse, mutect2, varscan2
- ZNF57 | c.1429G>C p.E477Q | Missense Mutation (SNP) | VAF 24/95 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.589); catalogued as COSV100182982; called by muse, mutect2, varscan2
- ZNF571 | c.754G>A p.E252K | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV100143887; called by muse, mutect2, varscan2
- ZNF644 | c.1798G>T p.V600F | Missense Mutation (SNP) | VAF 20/136 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.006); catalogued as COSV100494577; called by muse, mutect2, varscan2
- ZNF749 | c.92A>G p.H31R | Missense Mutation (SNP) | VAF 136/287 reads (47%) | SIFT tolerated (0.4); PolyPhen benign (0.011); catalogued as rs777588838, COSV100494408; called by muse, mutect2, varscan2
- ZNF804A | c.2657T>C p.L886P | Missense Mutation (SNP) | VAF 26/134 reads (19%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as COSV100168876, COSV100171087; called by muse, mutect2, varscan2
- ZNF813 | c.953G>T p.R318M | Missense Mutation (SNP) | VAF 23/180 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.835); catalogued as COSV101124919; called by muse, mutect2, varscan2
- ZNF835 | c.73G>A p.E25K | Missense Mutation (SNP) | VAF 13/118 reads (11%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs372399742, COSV101606372; called by muse, mutect2
- ZNF875 | c.1043A>T p.Q348L | Missense Mutation (SNP) | VAF 30/137 reads (22%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.575); catalogued as COSV100183423; called by muse, mutect2, varscan2
- ZNF99 | c.1441T>A p.Y481N | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV101233879; called by muse, varscan2
- ZSCAN4 | c.128C>G p.S43* | Nonsense Mutation (SNP) | VAF 17/159 reads (11%) | catalogued as rs1350112456, COSV100552542; called by muse, mutect2, varscan2
- ZSCAN5B | c.478G>C p.D160H | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs375625371; called by muse, mutect2, varscan2
- ZYG11B | c.976C>G p.Q326E | Missense Mutation (SNP) | VAF 45/184 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99597596; called by muse, mutect2, varscan2
- COL20A1 | c.3539G>T p.G1180V | Missense Mutation (SNP) | VAF 2/15 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CSMD2 | c.141del p.N48Ifs*264 | Frame Shift Del (DEL) | VAF 8/61 reads (13%) | called by mutect2, varscan2
- FMN2 | c.2636del p.P879Hfs*8 | Frame Shift Del (DEL) | VAF 16/126 reads (13%) | called by mutect2, varscan2
- GAST | c.208del p.A70Qfs*? | Frame Shift Del (DEL) | VAF 11/54 reads (20%) | called by mutect2, pindel, varscan2
- GSE1 | c.2486_2487delinsT p.P829Lfs*26 | Frame Shift Del (DEL) | VAF 36/175 reads (21%) | called by pindel, varscan2*
- IGKV6-21 | c.140G>C p.S47T | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.381); called by mutect2, varscan2
- KIR3DL1 | c.69G>T p.M23I | Missense Mutation (SNP) | VAF 51/324 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- KMT2D | c.6531dup p.G2178Wfs*24 | Frame Shift Ins (INS) | VAF 7/21 reads (33%) | called by mutect2, pindel, varscan2
- MICB | c.652G>C p.E218Q | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.358); called by muse, mutect2
- MUC2 | c.157A>G p.M53V | Missense Mutation (SNP) | VAF 51/213 reads (24%) | SIFT tolerated, low confidence (0.1); called by muse, mutect2, varscan2
- NEB | c.9574del p.L3192* | Frame Shift Del (DEL) | VAF 20/155 reads (13%) | called by mutect2, pindel, varscan2
- PCDHA9 | c.1260del p.Y421Tfs*28 | Frame Shift Del (DEL) | VAF 45/195 reads (23%) | called by mutect2, pindel, varscan2
- POLR2A | c.5570C>G p.S1857C | Missense Mutation (SNP) | VAF 76/211 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); called by muse, mutect2, varscan2
- SLIT3 | c.1974-4_1974-2delinsTT p.X658_splice | Splice Site (DEL) | VAF 18/86 reads (21%) | called by pindel, varscan2*
- THSD7A | c.1821dup p.G608Wfs*5 | Frame Shift Ins (INS) | VAF 7/48 reads (15%) | called by mutect2, pindel, varscan2
- TRAV8-2 | c.253G>A p.E85K | Missense Mutation (SNP) | VAF 25/113 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- ABCC3 | c.1236C>G p.L412= | Silent (SNP) | VAF 27/120 reads (23%) | catalogued as COSV99559431; called by muse, mutect2, varscan2
- ADPRHL1 | c.111G>T p.L37= | Silent (SNP) | VAF 36/97 reads (37%) | catalogued as COSV100215261; called by muse, mutect2, varscan2
- AKAP11 | c.264C>A p.L88= | Silent (SNP) | VAF 14/65 reads (22%) | catalogued as COSV99214112; called by muse, mutect2, varscan2
- ALDH1A1 | c.888C>T p.F296= | Silent (SNP) | VAF 67/174 reads (39%) | catalogued as COSV99921479; called by muse, mutect2, varscan2
- ALDH8A1 | c.342C>T p.F114= | Silent (SNP) | VAF 18/66 reads (27%) | catalogued as COSV99664853; called by muse, mutect2, varscan2
- ANO4 | c.774C>A p.A258= (on ENST00000392977 / NM_001286615.2; = p.A223= on NM_178826.4) | Silent (SNP) | VAF 7/55 reads (13%) | catalogued as COSV100153224; called by muse, mutect2, varscan2
- ANO7 | c.69G>A p.V23= | Silent (SNP) | VAF 15/64 reads (23%) | catalogued as COSV51471555; called by muse, mutect2, varscan2
- ARAP2 | c.984A>C p.S328= | Silent (SNP) | VAF 8/57 reads (14%) | catalogued as COSV100394906; called by muse, mutect2, varscan2
- ARHGAP31 | c.675G>A p.E225= | Silent (SNP) | VAF 31/134 reads (23%) | catalogued as COSV51801105; called by muse, mutect2, varscan2
- ATP4A | c.2991C>T p.F997= | Silent (SNP) | VAF 5/31 reads (16%) | catalogued as COSV99382822; called by muse, mutect2, varscan2
- C15orf39 | c.192G>C p.A64= | Silent (SNP) | VAF 14/41 reads (34%) | catalogued as rs777215863, COSV100641402, COSV62297184; called by muse, mutect2, varscan2
- C5AR1 | c.681C>A p.L227= | Silent (SNP) | VAF 48/202 reads (24%) | catalogued as rs143040550; called by muse, mutect2, varscan2
- CA8 | c.823C>A p.R275= | Silent (SNP) | VAF 16/98 reads (16%) | catalogued as COSV100527113, COSV58773308; called by muse, mutect2, varscan2
- CAPN15 | c.105C>G p.L35= | Silent (SNP) | VAF 7/44 reads (16%) | catalogued as COSV99562624; called by muse, mutect2, varscan2
- CCNB3 | c.690C>A p.S230= | Silent (SNP) | VAF 18/81 reads (22%) | catalogued as COSV52079702, COSV99329366; called by muse, mutect2, varscan2
- CD300E | c.528C>G p.L176= | Silent (SNP) | VAF 18/101 reads (18%) | catalogued as COSV100151386; called by muse, mutect2, varscan2
- CDHR1 | c.1968G>C p.V656= | Silent (SNP) | VAF 88/216 reads (41%) | catalogued as COSV100259139; called by muse, mutect2, varscan2
- CHST3 | c.114C>T p.I38= | Silent (SNP) | VAF 20/96 reads (21%) | catalogued as rs374590185, COSV64150635; called by muse, mutect2, varscan2
- COL4A4 | c.4677C>T p.I1559= | Silent (SNP) | VAF 13/53 reads (25%) | catalogued as COSV100306623, COSV100307265; called by muse, mutect2, varscan2
- CSNK1A1 | c.105C>T p.I35= | Silent (SNP) | VAF 17/64 reads (27%) | catalogued as COSV99939562; called by muse, varscan2
- CYLD | c.2682G>T p.R894= | Silent (SNP) | VAF 31/142 reads (22%) | catalogued as COSV100282604; called by muse, mutect2, varscan2
- DDB1 | c.1128C>T p.V376= | Silent (SNP) | VAF 28/202 reads (14%) | catalogued as COSV100074730; called by muse, mutect2
- DDX43 | c.1659C>A p.V553= | Silent (SNP) | VAF 26/130 reads (20%) | catalogued as COSV100944024; called by muse, mutect2, varscan2
- DDX60L | c.4320C>G p.L1440= | Silent (SNP) | VAF 17/76 reads (22%) | catalogued as COSV52708906, COSV99487935; called by muse, mutect2, varscan2
- DHH | c.300C>T p.T100= | Silent (SNP) | VAF 20/83 reads (24%) | catalogued as rs145131024; called by muse, mutect2, varscan2
- DKK2 | c.759C>A p.L253= | Silent (SNP) | VAF 26/127 reads (20%) | catalogued as COSV53400005, COSV99569156; called by muse, mutect2, varscan2
- DPEP1 | c.498C>T p.L166= | Silent (SNP) | VAF 12/69 reads (17%) | catalogued as COSV99878595; called by muse, mutect2, varscan2
- E4F1 | c.489G>T p.P163= | Silent (SNP) | VAF 38/140 reads (27%) | catalogued as rs771680213, COSV100065882, COSV57040754; called by muse, mutect2, varscan2
- EVC2 | c.2823G>T p.V941= | Silent (SNP) | VAF 12/53 reads (23%) | catalogued as COSV100186343, COSV100187236; called by muse, mutect2
- EXOSC4 | c.312C>T p.R104= | Silent (SNP) | VAF 66/113 reads (58%) | catalogued as COSV60155345; called by muse, mutect2, varscan2
- FAM110C | c.738C>T p.L246= | Silent (SNP) | VAF 5/26 reads (19%) | catalogued as rs577537646, COSV100566903; called by muse, mutect2, varscan2
- FASN | c.915G>C p.L305= | Silent (SNP) | VAF 6/38 reads (16%) | catalogued as COSV100148047; called by muse, mutect2, varscan2
- FBXO43 | c.1143G>C p.S381= | Silent (SNP) | VAF 27/173 reads (16%) | catalogued as rs375857020, COSV101413882; called by muse, mutect2, varscan2
- FFAR1 | c.477C>A p.G159= | Silent (SNP) | VAF 13/76 reads (17%) | catalogued as rs748238031, COSV99323458; called by muse, mutect2, varscan2
- FOXE3 | c.387C>T p.F129= | Silent (SNP) | VAF 21/111 reads (19%) | catalogued as COSV58632604; called by muse, mutect2, varscan2
- GAB4 | c.1044C>A p.G348= | Silent (SNP) | VAF 8/42 reads (19%) | catalogued as rs1173339199, COSV101272028; called by muse, mutect2, varscan2
- GALNT8 | c.1137C>T p.L379= | Silent (SNP) | VAF 25/110 reads (23%) | catalogued as COSV52897848; called by muse, mutect2, varscan2
- GLCCI1 | c.1554C>T p.A518= | Silent (SNP) | VAF 69/405 reads (17%) | catalogued as COSV99780548; called by muse, mutect2, varscan2
- GPC4 | c.1065C>T p.S355= | Silent (SNP) | VAF 90/450 reads (20%) | catalogued as COSV100895526; called by muse, varscan2
- HARS2 | c.909A>G p.L303= | Silent (SNP) | VAF 61/209 reads (29%) | catalogued as COSV99218124; called by muse, mutect2, varscan2
- HMCN1 | c.186G>C p.G62= | Silent (SNP) | VAF 18/86 reads (21%) | catalogued as COSV99632004; called by muse, mutect2, varscan2
- HOXA10 | c.189C>G p.V63= | Silent (SNP) | VAF 4/14 reads (29%) | catalogued as rs750857163, COSV99385565; called by muse, mutect2, varscan2
- HOXD4 | c.24G>A p.V8= | Silent (SNP) | VAF 24/122 reads (20%) | catalogued as COSV100106931; called by muse, mutect2, varscan2
- HPD | c.783C>T p.G261= | Silent (SNP) | VAF 6/43 reads (14%) | catalogued as rs369152577; called by muse, mutect2, varscan2
- HS3ST6 | c.615C>T p.R205= | Silent (SNP) | VAF 15/56 reads (27%) | catalogued as rs766740518, COSV53536655; called by muse, mutect2, varscan2
- HSD17B10 | c.318C>G p.G106= | Silent (SNP) | VAF 6/32 reads (19%) | catalogued as COSV99395031; called by muse, mutect2, varscan2
- HSD3B7 | c.648C>T p.L216= | Silent (SNP) | VAF 16/77 reads (21%) | catalogued as rs771503911, COSV99288230; called by muse, mutect2, varscan2
- IL19 | c.417C>A p.V139= | Silent (SNP) | VAF 11/59 reads (19%) | catalogued as COSV99536373; called by muse, mutect2, varscan2
- INF2 | c.2247C>T p.L749= | Silent (SNP) | VAF 11/43 reads (26%) | catalogued as COSV99384076; called by muse, mutect2, varscan2
- INPP5B | c.1584C>T p.L528= (on ENST00000373023; = p.L448= on NM_005540.3 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 10/59 reads (17%) | catalogued as COSV100886543; called by muse, mutect2, varscan2
- INTS7 | c.1869C>G p.L623= | Silent (SNP) | VAF 8/66 reads (12%) | catalogued as COSV100877538; called by muse, mutect2, varscan2
- ISLR2 | c.75C>T p.A25= | Silent (SNP) | VAF 16/113 reads (14%) | catalogued as rs752276896, COSV100679667; called by muse, mutect2, varscan2
- KCNH1 | c.852C>A p.P284= | Silent (SNP) | VAF 29/129 reads (22%) | catalogued as COSV99660127; called by muse, mutect2, varscan2
- KCNMB4 | c.327C>A p.T109= | Silent (SNP) | VAF 11/58 reads (19%) | catalogued as COSV99253297; called by muse, mutect2, varscan2
- KCTD13 | c.633C>G p.L211= | Silent (SNP) | VAF 16/58 reads (28%) | catalogued as COSV100442200, COSV58161827; called by muse, mutect2, varscan2
- KLF14 | c.777C>G p.L259= | Silent (SNP) | VAF 4/19 reads (21%) | catalogued as COSV100205941; called by muse, mutect2, varscan2
- KMT2A | c.5805C>T p.F1935= | Silent (SNP) | VAF 114/439 reads (26%) | catalogued as COSV100629255, COSV100629816; called by muse, mutect2, varscan2
- LDLRAD3 | c.654C>A p.S218= | Silent (SNP) | VAF 16/86 reads (19%) | catalogued as COSV100214870; called by muse, mutect2, varscan2
- LIG1 | c.1920C>T p.T640= | Silent (SNP) | VAF 75/372 reads (20%) | catalogued as rs1400805952, COSV54392075, COSV99619101; called by muse, mutect2, varscan2
- LILRB2 | c.1386G>T p.V462= | Silent (SNP) | VAF 61/122 reads (50%) | catalogued as COSV100079469; called by muse, mutect2, varscan2
- LSR | c.660G>T p.V220= | Silent (SNP) | VAF 26/93 reads (28%) | catalogued as COSV100670526; called by muse, mutect2, varscan2
- MASP1 | c.63C>A p.T21= | Silent (SNP) | VAF 17/126 reads (13%) | catalogued as COSV51463324, COSV99397385; called by muse, mutect2, varscan2
- MATN4 | c.1227G>A p.V409= (on ENST00000372754; = p.V368= on NM_003833.4) | Silent (SNP) | VAF 19/105 reads (18%) | catalogued as rs200187459, COSV100637094; called by muse, mutect2, varscan2
- MCOLN2 | c.871C>T p.L291= | Silent (SNP) | VAF 9/45 reads (20%) | catalogued as COSV99394049; called by muse, mutect2, varscan2
- MED13L | c.2016C>G p.L672= | Silent (SNP) | VAF 19/93 reads (20%) | catalogued as rs530164873, COSV56125844, COSV99929413; called by muse, mutect2, varscan2
- MED15 | c.1335G>T p.P445= (on ENST00000263205 / NM_001003891.3; = p.P405= on NM_015889.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 4/15 reads (27%) | catalogued as COSV99487405; called by muse, mutect2
- MLLT10 | c.147C>G p.V49= | Silent (SNP) | VAF 9/65 reads (14%) | catalogued as COSV100308397; called by muse, mutect2, varscan2
- MMP15 | c.1224C>T p.I408= | Silent (SNP) | VAF 18/69 reads (26%) | catalogued as rs907458455, COSV54679728; called by muse, mutect2, varscan2
- MTMR10 | c.18G>T p.P6= | Silent (SNP) | VAF 29/81 reads (36%) | catalogued as rs1281978886, COSV101437411; called by muse, mutect2, varscan2
- MYH9 | c.1170C>T p.L390= | Silent (SNP) | VAF 53/296 reads (18%) | catalogued as COSV99339304; called by muse, mutect2, varscan2
- MYO3B | c.366C>G p.L122= | Silent (SNP) | VAF 13/81 reads (16%) | catalogued as COSV100510816; called by muse, mutect2, varscan2
- MYO3B | c.927G>A p.K309= | Silent (SNP) | VAF 20/100 reads (20%) | catalogued as COSV58722416; called by muse, mutect2, varscan2
- MYOD1 | c.513C>A p.P171= | Silent (SNP) | VAF 7/41 reads (17%) | catalogued as rs1401285310, COSV100000323; called by muse, mutect2, varscan2
- NAA11 | c.258G>T p.L86= | Silent (SNP) | VAF 15/102 reads (15%) | catalogued as COSV99727460; called by muse, mutect2, varscan2
- NAIP | c.270G>C p.G90= | Silent (SNP) | VAF 15/201 reads (7%) | catalogued as COSV99519371; called by muse, mutect2
- NBPF1 | c.213G>A p.L71= | Silent (SNP) | VAF 27/365 reads (7%) | catalogued as rs1443086397, COSV101236496; called by muse, varscan2
- NEDD4L | c.2451G>A p.V817= (on ENST00000400345 / NM_001144967.3; = p.V797= on NM_015277.6) | Silent (SNP) | VAF 10/79 reads (13%) | catalogued as COSV99895631; called by muse, mutect2, varscan2
- NRSN1 | c.351G>T p.L117= | Silent (SNP) | VAF 26/93 reads (28%) | catalogued as COSV101027327; called by muse, mutect2, varscan2
- NTN3 | c.579C>T p.F193= | Silent (SNP) | VAF 4/24 reads (17%) | catalogued as COSV99565109; called by mutect2, varscan2
- OR10K2 | c.474C>T p.I158= | Silent (SNP) | VAF 38/141 reads (27%) | catalogued as COSV59222728; called by muse, mutect2, varscan2
- OR1M1 | c.435C>T p.V145= | Silent (SNP) | VAF 24/157 reads (15%) | catalogued as rs1359902619, COSV70036753; called by muse, varscan2
- OR2Y1 | c.604C>A p.R202= | Silent (SNP) | VAF 23/80 reads (29%) | catalogued as COSV57137201, COSV57138015; called by muse, mutect2, varscan2
- OR5K4 | c.867G>C p.L289= | Silent (SNP) | VAF 44/261 reads (17%) | catalogued as COSV61583514, COSV61584415; called by muse, mutect2, varscan2
- OR9K2 | c.960C>G p.V320= (on ENST00000305377; = p.V298= on NM_001005243.1) | Silent (SNP) | VAF 14/68 reads (21%) | catalogued as COSV100543871; called by muse, mutect2, varscan2
- PABPC5 | c.807C>G p.L269= | Silent (SNP) | VAF 28/112 reads (25%) | catalogued as COSV100442519; called by muse, mutect2, varscan2
- PACS1 | c.1539G>T p.L513= | Silent (SNP) | VAF 21/106 reads (20%) | catalogued as COSV100270289; called by muse, mutect2, varscan2
- PCDH11X | c.1458G>T p.T486= | Silent (SNP) | VAF 27/119 reads (23%) | catalogued as COSV100013013, COSV53501258; called by muse, mutect2, varscan2
- PCDHB8 | c.1317C>G p.T439= | Silent (SNP) | VAF 51/225 reads (23%) | catalogued as rs554876965, COSV50760425, COSV99177135; called by muse, mutect2, varscan2
- PHGDH | c.372G>A p.A124= | Silent (SNP) | VAF 19/99 reads (19%) | catalogued as rs146740411; ClinVar: conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- PICALM | c.1785C>T p.P595= | Silent (SNP) | VAF 14/57 reads (25%) | catalogued as COSV100707999; called by muse, mutect2, varscan2
- PIEZO2 | c.6738G>T p.V2246= | Silent (SNP) | VAF 25/102 reads (25%) | catalogued as COSV53286711, COSV99555207; called by muse, mutect2, varscan2
- PKHD1L1 | c.11472G>A p.L3824= | Silent (SNP) | VAF 82/225 reads (36%) | catalogued as rs1429932899, COSV101006545; called by muse, mutect2, varscan2
- POLD1 | c.285C>T p.I95= | Silent (SNP) | VAF 13/77 reads (17%) | catalogued as COSV101486896; called by muse, mutect2, varscan2
- PRPF3 | c.2037A>G p.L679= | Silent (SNP) | VAF 51/215 reads (24%) | catalogued as rs1426657168, COSV100254916; called by muse, mutect2, varscan2
- PRR14 | c.795C>T p.L265= | Silent (SNP) | VAF 8/52 reads (15%) | catalogued as COSV99788533; called by muse, mutect2, varscan2
- PSG1 | c.678C>T p.S226= | Silent (SNP) | VAF 95/543 reads (17%) | catalogued as COSV99739387; called by muse, mutect2, varscan2
- RAB8A | c.375G>A p.V125= | Silent (SNP) | VAF 13/48 reads (27%) | catalogued as rs372506210; called by muse, mutect2, varscan2
- RELN | c.699G>A p.A233= | Silent (SNP) | VAF 17/93 reads (18%) | catalogued as rs780491620, COSV58988520, COSV58993933; ClinVar: likely benign; called by muse, mutect2, varscan2
- RFC4 | c.1044C>A p.L348= | Silent (SNP) | VAF 12/76 reads (16%) | catalogued as COSV56217090, COSV99961279; called by muse, mutect2, varscan2
- RIPK1 | c.1347G>T p.V449= | Silent (SNP) | VAF 18/71 reads (25%) | catalogued as COSV99454601; called by muse, mutect2, varscan2
- RNF39 | c.27G>C p.L9= | Silent (SNP) | VAF 25/126 reads (20%) | catalogued as COSV99748546; called by muse, mutect2, varscan2
- RRAGB | c.963T>C p.A321= (on ENST00000262850 / NM_016656.4; = p.A293= on NM_006064.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 6/40 reads (15%) | catalogued as rs776175904, COSV99469483; called by muse, mutect2, varscan2
- SAMD1 | c.1298G>A p.*433= | Silent (SNP) | VAF 30/132 reads (23%) | catalogued as COSV99513878, COSV99513905; called by muse, mutect2, varscan2
- SEMA3C | c.1302G>T p.V434= | Silent (SNP) | VAF 42/190 reads (22%) | catalogued as COSV99543341; called by muse, mutect2
- SEMA3D | c.933A>C p.S311= | Silent (SNP) | VAF 47/271 reads (17%) | catalogued as COSV99407007; called by muse, mutect2, varscan2
- SEPTIN5 | c.561C>A p.L187= | Silent (SNP) | VAF 21/83 reads (25%) | catalogued as COSV100820429; called by muse, mutect2, varscan2
- SLC16A10 | c.1437G>A p.E479= | Silent (SNP) | VAF 8/94 reads (9%) | catalogued as COSV64356272; called by muse, mutect2
- SLC34A2 | c.177G>C p.L59= | Silent (SNP) | VAF 26/117 reads (22%) | catalogued as COSV101158417; called by muse, mutect2, varscan2
- SLC39A1 | c.492G>T p.G164= | Silent (SNP) | VAF 19/97 reads (20%) | catalogued as rs201116490, COSV100135593; called by muse, mutect2, varscan2
- SLCO1C1 | c.459G>T p.P153= | Silent (SNP) | VAF 16/124 reads (13%) | catalogued as COSV99859470; called by muse, mutect2
- SLCO5A1 | c.1302C>T p.F434= | Silent (SNP) | VAF 53/103 reads (51%) | catalogued as rs759742123, COSV99480436; called by muse, mutect2, varscan2
- SMARCC2 | c.2736C>T p.I912= | Silent (SNP) | VAF 24/144 reads (17%) | catalogued as rs890097490, COSV57218245; called by muse, varscan2
- SMARCC2 | c.2652C>T p.I884= | Silent (SNP) | VAF 18/106 reads (17%) | catalogued as rs1273993462, COSV99911601; called by muse, varscan2
- SNX20 | c.807G>C p.L269= | Silent (SNP) | VAF 11/66 reads (17%) | catalogued as COSV100319262; called by muse, mutect2, varscan2
- SOX6 | c.1701C>G p.V567= (on ENST00000528429 / NM_001145819.2; = p.V540= on NM_017508.3) | Silent (SNP) | VAF 6/40 reads (15%) | catalogued as COSV100322611; called by muse, mutect2, varscan2
- SPEG | c.6576A>T p.A2192= | Silent (SNP) | VAF 15/98 reads (15%) | catalogued as COSV100405007; called by muse, mutect2, varscan2
- SPEN | c.6375G>A p.E2125= | Silent (SNP) | VAF 40/188 reads (21%) | catalogued as COSV101005396; called by muse, mutect2
- SPEN | c.8466G>A p.Q2822= | Silent (SNP) | VAF 14/66 reads (21%) | catalogued as rs138278143, COSV65357612; called by muse, mutect2, varscan2
- SRGAP2 | c.2088G>A p.E696= (on ENST00000624873 / NM_001170637.4; = p.E697= on NM_015326.5 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 46/219 reads (21%) | catalogued as COSV99833023; called by muse, mutect2, varscan2
- SRRM2 | c.3405G>A p.Q1135= | Silent (SNP) | VAF 32/162 reads (20%) | catalogued as COSV100071086; called by muse, mutect2, varscan2
- STAP2 | c.213C>T p.L71= | Silent (SNP) | VAF 18/78 reads (23%) | catalogued as COSV101654924, COSV74075493; called by muse, mutect2, varscan2
- SYBU | c.177C>A p.P59= (on ENST00000276646 / NM_001099754.2; = p.P58= on NM_017786.6) | Silent (SNP) | VAF 22/115 reads (19%) | catalogued as COSV99406383; called by muse, mutect2, varscan2
- SYNE1 | c.6468G>A p.L2156= (on ENST00000367255 / NM_182961.4; = p.L2163= on NM_033071.3) | Silent (SNP) | VAF 12/68 reads (18%) | catalogued as COSV99571210; called by muse, mutect2, varscan2
- TANC1 | c.4020C>G p.L1340= | Silent (SNP) | VAF 21/128 reads (16%) | catalogued as COSV99714521; called by muse, mutect2, varscan2
- TBCE | c.1257C>G p.L419= (on ENST00000366601; = p.L482= on NM_003193.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 26/153 reads (17%) | catalogued as COSV64004593; called by muse, mutect2, varscan2
- TDRD5 | c.2682A>G p.E894= | Silent (SNP) | VAF 18/102 reads (18%) | catalogued as rs1362283168, COSV99676650; called by muse, mutect2, varscan2
- TFAP2D | c.714C>T p.L238= | Silent (SNP) | VAF 26/112 reads (23%) | catalogued as COSV99146066; called by muse, mutect2, varscan2
- TNFRSF1A | c.1134A>G p.L378= | Silent (SNP) | VAF 5/25 reads (20%) | catalogued as rs1347200386, COSV99164479; called by muse, mutect2, varscan2
- TOPBP1 | c.1758G>C p.L586= | Silent (SNP) | VAF 18/80 reads (23%) | catalogued as COSV99605536; called by muse, varscan2
- TSBP1 | c.789G>A p.L263= (on ENST00000617061; = p.L266= on NM_006781.5) | Silent (SNP) | VAF 35/143 reads (24%) | catalogued as COSV100898863; called by muse, mutect2, varscan2
- TTLL4 | c.1257C>T p.I419= | Silent (SNP) | VAF 28/115 reads (24%) | catalogued as COSV99293511; called by muse, mutect2, varscan2
- TTN | c.83535G>A p.L27845= (on ENST00000591111; = p.L20421= on NM_003319.4) | Silent (SNP) | VAF 12/51 reads (24%) | catalogued as rs1195614492, COSV100620365; called by muse, mutect2, varscan2
- TUBB4A | c.1038C>A p.P346= | Silent (SNP) | VAF 93/339 reads (27%) | catalogued as COSV51153173, COSV99900059; called by muse, mutect2, varscan2
- TUBB6 | c.621C>G p.L207= | Silent (SNP) | VAF 37/179 reads (21%) | catalogued as rs780101902, COSV99302041; called by muse, mutect2, varscan2
- TVP23C | c.729C>G p.L243= | Silent (SNP) | VAF 6/29 reads (21%) | catalogued as COSV56670012, COSV99846953; called by muse, mutect2, varscan2
- UPB1 | c.543C>A p.A181= | Silent (SNP) | VAF 14/62 reads (23%) | catalogued as COSV100387224; called by muse, mutect2, varscan2
- USP40 | c.2058C>T p.V686= | Silent (SNP) | VAF 46/225 reads (20%) | catalogued as rs1430927286, COSV99296717; called by muse, mutect2, varscan2
- UTP14A | c.1806T>C p.D602= | Silent (SNP) | VAF 15/54 reads (28%) | catalogued as COSV100928984; called by muse, mutect2, varscan2
- VIP | c.213C>A p.P71= | Silent (SNP) | VAF 12/59 reads (20%) | catalogued as COSV100923947; called by muse, mutect2, varscan2
- VSIG4 | c.444C>T p.G148= | Silent (SNP) | VAF 14/47 reads (30%) | catalogued as COSV101038207; called by muse, mutect2, varscan2
- WDR83 | c.947G>A p.*316= | Silent (SNP) | VAF 8/30 reads (27%) | catalogued as COSV99269654; called by muse, mutect2, varscan2
- ZFPM2 | c.495G>T p.V165= | Silent (SNP) | VAF 28/50 reads (56%) | catalogued as COSV101342970; called by muse, mutect2, varscan2
- ZMYND8 | c.1197C>G p.L399= (on ENST00000311275 / NM_001363741.2; = p.L419= on NM_012408.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 35/220 reads (16%) | catalogued as COSV99520896; called by muse, mutect2, varscan2
- ZNF398 | c.1278T>C p.P426= (on ENST00000475153 / NM_170686.3; = p.P255= on NM_020781.4) | Silent (SNP) | VAF 52/214 reads (24%) | catalogued as COSV100246971; called by muse, mutect2, varscan2
- ZNF559 | c.1497G>C p.G499= | Silent (SNP) | VAF 33/115 reads (29%) | catalogued as COSV100416622; called by muse, mutect2, varscan2
- ZNF655 | c.1035A>G p.L345= | Silent (SNP) | VAF 34/141 reads (24%) | catalogued as COSV99402222; called by muse, mutect2, varscan2
- ANKMY1 | chr2:240560750 C>G | 5'Flank (SNP) | VAF 6/16 reads (38%) | catalogued as COSV56031346; called by muse, mutect2, varscan2
- CHCHD2P9 | n.11G>A | RNA (SNP) | VAF 18/99 reads (18%) | called by muse, mutect2, varscan2
- CLDND1 | c.-18-252G>T | Intron (SNP) | VAF 7/34 reads (21%) | catalogued as COSV100360762, COSV57858376; called by muse, mutect2, varscan2
- GLOD4 | chr17:782477 G>A | 5'Flank (SNP) | VAF 11/29 reads (38%) | catalogued as COSV56754201; called by muse, mutect2, varscan2
- GLRXP3 | n.135T>C | RNA (SNP) | VAF 38/178 reads (21%) | called by muse, mutect2, varscan2
- HSP90AB1 | c.*123C>G | 3'UTR (SNP) | VAF 10/42 reads (24%) | catalogued as COSV99241235; called by muse, mutect2, varscan2
- IKBIP | c.297+7689C>G | Intron (SNP) | VAF 27/98 reads (28%) | catalogued as COSV54488890, COSV54490905; called by muse, mutect2, varscan2
- KIR3DX1 | n.1061C>T | RNA (SNP) | VAF 29/99 reads (29%) | called by muse, varscan2
- SSPOP | n.8097G>T | RNA (SNP) | VAF 4/11 reads (36%) | catalogued as COSV100947662, COSV65136941; called by muse, mutect2, varscan2
- TM2D2 | c.228-18_228-17dup | Intron (INS) | VAF 55/177 reads (31%) | called by mutect2, pindel, varscan2
- TMEM236 | c.*2146A>T | 3'UTR (SNP) | VAF 20/98 reads (20%) | catalogued as COSV100592570; called by mutect2, varscan2
